Somatic mutation profile of tumor specimen TCGA-DU-6407-02B (aliquot TCGA-DU-6407-02B-11D-A36O-08) from TCGA case TCGA-DU-6407, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Oligodendroglioma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 35.6 years (13,021 days).
Specimen TCGA-DU-6407-02B: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b467f2a1-ae27-46f2-856b-4c935f733ca5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DU-6407-10A (Blood Derived Normal), aliquot TCGA-DU-6407-10A-01D-1705-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d9e82805-6c2e-45d9-a750-47c3650e2c3e

The open-access MAF lists 2,299 somatic variants for this specimen: 1,550 protein-altering or splice-affecting, 695 silent, 54 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,411, Silent 695, Splice Site 59, Nonsense Mutation 54, Intron 26, Splice Region 19, 3'UTR 12, RNA 9, Frame Shift Del 5, 5'UTR 3, In Frame Del 2, 3'Flank 2.

Variants (750 of 2,299; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRCA2 | c.8910G>A p.W2970* | Nonsense Mutation (SNP) | VAF 21/73 reads (29%) | catalogued as rs886040799, COSV101204649; ClinVar: pathogenic; called by muse, mutect2, varscan2
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 36/100 reads (36%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- MSH6 | c.3656C>T p.T1219I | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs63750949, CM020039, COSV52276093; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- NIPAL4 | c.470G>A p.G157E | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs900769357, COSV100357319; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.325T>G p.F109V | Missense Mutation (SNP) | VAF 66/75 reads (88%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1057523496, COSV52819746, COSV53616876; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- WAC | c.1198C>T p.Q400* | Nonsense Mutation (SNP) | VAF 45/224 reads (20%) | catalogued as rs1064796758, COSV61567444; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AAAS | c.1636C>T p.L546F | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); catalogued as COSV99267122; called by muse, varscan2
- AARS1 | c.1742G>A p.G581D | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1308559016, COSV55746817, COSV99933801; called by muse, mutect2, varscan2
- ABAT | c.385C>T p.P129S | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.903); catalogued as COSV99191033; called by muse, mutect2, varscan2
- ABAT | c.989C>T p.T330I | Missense Mutation (SNP) | VAF 36/100 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99191034; called by muse, mutect2, varscan2
- ABCA12 | c.3829+1G>A p.X1277_splice (on ENST00000272895 / NM_173076.3; = p.X959_splice on NM_015657.3) | Splice Site (SNP) | VAF 18/58 reads (31%) | catalogued as CS080640; called by muse, mutect2
- ABCA6 | c.3487C>T p.P1163S | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV52639973, COSV99447706; called by muse, mutect2, varscan2
- ABCA9 | c.2359G>A p.V787M | Missense Mutation (SNP) | VAF 26/140 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs201495945, COSV100383491; called by muse, mutect2, varscan2
- ABCB7 | c.1571C>T p.P524L (on ENST00000373394 / NM_001271696.3; = p.P525L on NM_004299.6) | Missense Mutation (SNP) | VAF 34/106 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.513); catalogued as COSV99504826; called by muse, mutect2, varscan2
- ABCC12 | c.1493G>A p.S498N | Missense Mutation (SNP) | VAF 43/116 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1380519794, COSV100253244; called by muse, mutect2, varscan2
- ABCC2 | c.1231G>A p.A411T | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT tolerated (0.24); PolyPhen benign (0.03); catalogued as COSV100966714; called by muse, mutect2, varscan2
- ABCC2 | c.4259C>T p.A1420V | Missense Mutation (SNP) | VAF 17/148 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.395); catalogued as COSV100966716; called by muse, mutect2, varscan2
- ABCF1 | c.343+1G>A p.X115_splice | Splice Site (SNP) | VAF 15/79 reads (19%) | catalogued as COSV100401061; called by muse, mutect2, varscan2
- ABI3 | c.952C>T p.P318S | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.979); catalogued as rs756129561, COSV99865819; called by muse, mutect2, varscan2
- ABL2 | c.490C>T p.P164S (on ENST00000502732 / NM_007314.4; = p.P149S on NM_005158.5) | Missense Mutation (SNP) | VAF 34/106 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.652); catalogued as COSV100773036; called by muse, mutect2, varscan2
- ACACB | c.6319G>A p.A2107T | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.69); PolyPhen benign (0.003); catalogued as rs761460741, COSV100623304; called by muse, varscan2
- ACAN | c.331G>A p.A111T | Missense Mutation (SNP) | VAF 57/170 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs867952487, COSV100719299, COSV61364611; called by muse, mutect2, varscan2
- ACBD6 | c.59G>A p.S20N | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.702); catalogued as COSV100852584; called by muse, mutect2, varscan2
- ACO1 | c.911G>A p.G304E | Missense Mutation (SNP) | VAF 128/349 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770327588, COSV100008649; called by muse, mutect2, varscan2
- ACO1 | c.1072G>A p.V358I | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs774323213, COSV100008487; called by muse, mutect2, varscan2
- ACTB | c.590G>A p.G197D | Missense Mutation (SNP) | VAF 30/120 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.683); catalogued as COSV59319076; called by muse, mutect2, varscan2
- ACTC1 | c.314C>T p.T105I | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT tolerated, low confidence (0.23); PolyPhen probably damaging (0.997); catalogued as rs1368192263, COSV51759788; called by muse, mutect2, varscan2
- ACTN1 | c.2147G>A p.G716D | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); catalogued as COSV99518531; called by muse, mutect2, varscan2
- ADAM21 | c.1348C>T p.L450F | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV99961472; called by muse, mutect2, varscan2
- ADAM29 | c.1457C>T p.P486L | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.247); catalogued as rs1263901899, COSV63668694; called by muse, mutect2, varscan2
- ADAMTS15 | c.1007G>A p.G336D | Missense Mutation (SNP) | VAF 34/98 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1334437301, COSV100143779, COSV54504335; called by muse, mutect2, varscan2
- ADAMTS9 | c.2446G>A p.A816T | Missense Mutation (SNP) | VAF 14/107 reads (13%) | SIFT tolerated (0.54); PolyPhen benign (0.023); catalogued as rs1302037800, COSV99900209; called by muse, mutect2, varscan2
- ADAMTSL3 | c.1461G>A p.W487* | Nonsense Mutation (SNP) | VAF 8/53 reads (15%) | catalogued as COSV99717584, COSV99721200; called by muse, mutect2
- ADCY10 | c.1625C>T p.A542V | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as COSV100897094; called by muse, mutect2, varscan2
- ADCY2 | c.1792C>T p.P598S | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV100604129, COSV57898783; called by muse, mutect2, varscan2
- ADGRA3 | c.1443G>A p.E481= | Splice Region (SNP) | VAF 6/66 reads (9%) | catalogued as rs1239060075, COSV99293794; called by muse, mutect2
- ADGRF3 | c.976G>A p.V326M (on ENST00000311519 / NM_001145168.1; = p.V127M on NM_153835.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.343); catalogued as rs982547659, COSV100275450; called by muse, mutect2, varscan2
- ADGRF4 | c.1834C>T p.P612S | Missense Mutation (SNP) | VAF 38/116 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99349020; called by muse, mutect2, varscan2
- ADGRL1 | c.1003G>A p.D335N (on ENST00000340736 / NM_001008701.3; = p.D330N on NM_014921.5) | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (0.47); PolyPhen benign (0.253); catalogued as rs944487739, COSV100529814; called by muse, mutect2, varscan2
- ADGRV1 | c.4610G>A p.G1537E | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); catalogued as COSV101316509; called by muse, mutect2, varscan2
- AFG3L2 | c.918G>C p.K306N | Missense Mutation (SNP) | VAF 36/93 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.019); catalogued as COSV99302186; called by muse, mutect2, varscan2
- AGL | c.2158G>A p.V720M | Missense Mutation (SNP) | VAF 9/111 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99650035; called by muse, mutect2
- AGO2 | c.1802C>T p.P601L | Missense Mutation (SNP) | VAF 56/198 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1272554221, COSV99596403; called by muse, mutect2, varscan2
- AGRN | c.1603G>A p.D535N | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.69); catalogued as rs1268548286, COSV101039079; called by muse, varscan2
- AHNAK | c.16796G>A p.G5599E | Missense Mutation (SNP) | VAF 64/175 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99949601; called by muse, mutect2, varscan2
- AHNAK | c.14297C>T p.T4766I | Missense Mutation (SNP) | VAF 103/341 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs1224441429, COSV99949603; called by muse, mutect2, varscan2
- AHNAK | c.10711G>A p.D3571N | Missense Mutation (SNP) | VAF 19/291 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.616); catalogued as COSV99949605; called by muse, mutect2
- AKAP11 | c.391C>T p.P131S | Missense Mutation (SNP) | VAF 38/59 reads (64%) | SIFT tolerated (0.08); PolyPhen benign (0.014); catalogued as COSV99214342; called by muse, mutect2, varscan2
- AKAP13 | c.4984G>A p.D1662N (on ENST00000394518 / NM_007200.5; = p.D1666N on NM_006738.6) | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT tolerated (0.18); PolyPhen benign (0.323); catalogued as COSV100774695; called by muse, mutect2, varscan2
- AKR1C2 | c.767C>T p.A256V | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.384); catalogued as COSV101060541; called by mutect2, varscan2
- AKR1E2 | c.59C>T p.T20I | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.583); catalogued as COSV100033689; called by muse, mutect2, varscan2
- ALG12 | c.1402C>T p.P468S | Missense Mutation (SNP) | VAF 15/59 reads (25%) | PolyPhen probably damaging (0.974); catalogued as rs753449100, COSV100427215, COSV58206559; called by muse, mutect2, varscan2
- ALPK3 | c.1517C>T p.P506L | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.003); catalogued as COSV99362012; called by muse, mutect2, varscan2
- ALS2 | c.1114C>T p.P372S | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as rs1442002766, COSV99970067; called by muse, mutect2, varscan2
- ALS2CL | c.1858G>A p.E620K | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); catalogued as rs775403542, COSV100015318; called by muse, mutect2, varscan2
- AMER2 | c.1282C>T p.P428S | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV100766387; called by muse, mutect2, varscan2
- AMY1C | c.1079C>T p.P360L | Missense Mutation (SNP) | VAF 29/269 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.027); catalogued as COSV100915238; called by muse, mutect2, varscan2
- ANK2 | c.2462C>T p.T821I | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.36); PolyPhen benign (0.041); catalogued as rs1248936595, COSV100004245; called by muse, mutect2, varscan2
- ANKFY1 | c.949G>A p.A317T | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.61); PolyPhen possibly damaging (0.664); catalogued as rs577444406, COSV100493174; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.1636G>A p.G546R | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1161823420, COSV99784474; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.5438C>T p.T1813I | Missense Mutation (SNP) | VAF 14/160 reads (9%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.021); catalogued as COSV99784482; called by muse, mutect2
- ANKRD17 | c.571G>A p.D191N | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.767); catalogued as COSV100429979; called by muse, mutect2, varscan2
- ANKZF1 | c.635C>T p.A212V | Missense Mutation (SNP) | VAF 15/208 reads (7%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.79); catalogued as COSV99850912; called by muse, mutect2
- ANLN | c.532G>A p.E178K | Missense Mutation (SNP) | VAF 29/122 reads (24%) | SIFT tolerated (0.25); PolyPhen benign (0.159); catalogued as rs28657426, COSV99732883; called by muse, mutect2, varscan2
- ANLN | c.3078+1G>A p.X1026_splice | Splice Site (SNP) | VAF 5/27 reads (19%) | catalogued as rs1354264170, COSV99732884; called by muse, mutect2
- ANTXR1 | c.1075G>A p.A359T | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as rs372820177; called by muse, mutect2, varscan2
- ANXA13 | c.409G>A p.E137K | Missense Mutation (SNP) | VAF 43/122 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774864225, COSV51624598; called by muse, mutect2, varscan2
- AOC3 | c.2041G>A p.G681S | Missense Mutation (SNP) | VAF 26/185 reads (14%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.714); catalogued as COSV100396240; called by muse, mutect2, varscan2
- AP3B1 | c.457C>T p.L153F | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99672462; called by muse, mutect2, varscan2
- AP4E1 | c.1426G>A p.E476K | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV55915597; called by muse, mutect2, varscan2
- APEX1 | c.239G>A p.G80E | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV99164519; called by muse, mutect2, varscan2
- APOB | c.8793G>A p.W2931* | Nonsense Mutation (SNP) | VAF 11/172 reads (6%) | catalogued as COSV99268081; called by muse, mutect2
- APOBEC3G | c.719G>A p.G240D | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV101349114; called by muse, mutect2, varscan2
- AQP3 | c.434G>A p.G145D | Missense Mutation (SNP) | VAF 49/124 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99955701; called by muse, mutect2, varscan2
- AR | c.1498C>T p.P500S | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.026); catalogued as COSV101019497; called by muse, mutect2, varscan2
- ARFGAP2 | c.710G>A p.S237N | Missense Mutation (SNP) | VAF 7/85 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.958); catalogued as COSV100125685; called by muse, mutect2
- ARHGAP11A | c.130G>A p.G44S | Missense Mutation (SNP) | VAF 32/145 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.069); catalogued as rs556056913, COSV100853360; called by muse, mutect2, varscan2
- ARHGAP17 | c.964+1G>A p.X322_splice | Splice Site (SNP) | VAF 44/100 reads (44%) | catalogued as COSV51510458; called by muse, mutect2, varscan2
- ARHGAP24 | c.481G>A p.D161N (on ENST00000395184 / NM_001025616.3; = p.D68N on NM_031305.3) | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as rs1388808126, COSV99982464; called by muse, mutect2, varscan2
- ARHGAP25 | c.1099C>T p.Q367* (on ENST00000409202 / NM_001007231.3; = p.Q359* on NM_014882.3) | Nonsense Mutation (SNP) | VAF 50/139 reads (36%) | catalogued as COSV99772142; called by muse, mutect2, varscan2
- ARHGAP9 | c.674C>T p.P225L | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs1234357730, COSV100712532, COSV62722232; called by muse, mutect2, varscan2
- ARHGEF12 | c.1305C>T p.H435= | Splice Region (SNP) | VAF 25/96 reads (26%) | catalogued as COSV100755208; called by muse, mutect2, varscan2
- ARHGEF16 | c.1924G>A p.A642T | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs956193838, COSV65683805; called by muse, mutect2, varscan2
- ARID5A | c.1237C>T p.P413S | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); catalogued as COSV100673645; called by muse, mutect2, varscan2
- ARID5B | c.1382C>T p.P461L | Missense Mutation (SNP) | VAF 8/184 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.244); catalogued as COSV54424330; called by muse, mutect2
- ARIH2 | c.523G>A p.D175N | Missense Mutation (SNP) | VAF 32/99 reads (32%) | SIFT tolerated (0.25); PolyPhen benign (0.021); catalogued as rs1399500675, COSV100711407; called by muse, mutect2, varscan2
- ARIH2 | c.1409G>A p.G470E | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV62706605; called by muse, mutect2, varscan2
- ARMCX5 | c.455G>T p.R152I | Missense Mutation (SNP) | VAF 58/171 reads (34%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV99863553; called by muse, mutect2, varscan2
- ARMCX5-GPRASP2 | c.877G>A p.D293N | Missense Mutation (SNP) | VAF 46/141 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.056); catalogued as COSV100771992; called by muse, mutect2, varscan2
- ARPIN | c.302-1G>A p.X101_splice | Splice Site (SNP) | VAF 16/43 reads (37%) | catalogued as COSV100673484; called by muse, varscan2
- ARRDC3 | c.517C>T p.Q173* | Nonsense Mutation (SNP) | VAF 8/102 reads (8%) | catalogued as COSV99475396; called by muse, mutect2
- ARVCF | c.1829G>A p.R610K | Missense Mutation (SNP) | VAF 29/92 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99599529; called by muse, mutect2, varscan2
- AS3MT | c.814C>T p.Q272* | Nonsense Mutation (SNP) | VAF 12/110 reads (11%) | catalogued as COSV100185879; called by muse, mutect2, varscan2
- ASB17 | c.412C>T p.P138S | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV99408072; called by muse, mutect2, varscan2
- ASB4 | c.1024G>A p.V342I | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT tolerated (0.47); PolyPhen benign (0.082); catalogued as COSV57945266; called by muse, mutect2, varscan2
- ASB4 | c.1267G>A p.G423R | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs753855421, COSV100367305; called by muse, mutect2, varscan2
- ASRGL1 | c.509G>A p.G170D | Missense Mutation (SNP) | VAF 16/192 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100078170; called by muse, mutect2
- ASTL | c.183G>A p.G61= | Splice Region (SNP) | VAF 6/17 reads (35%) | catalogued as rs144520713, COSV100668446; called by muse, mutect2, varscan2
- ASTN1 | c.1274G>A p.S425N | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.709); catalogued as COSV56067489, COSV99923073; called by mutect2, varscan2
- ASTN2 | c.1117C>T p.P373S | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.007); catalogued as COSV100530345; called by muse, mutect2, varscan2
- ATF7IP | c.1963G>A p.A655T | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.933); catalogued as COSV99662128; called by muse, mutect2, varscan2
- ATG2A | c.5726C>T p.S1909F | Missense Mutation (SNP) | VAF 36/85 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100815544; called by muse, mutect2, varscan2
- ATG9A | c.1849-1G>A p.X617_splice | Splice Site (SNP) | VAF 27/87 reads (31%) | catalogued as COSV99522261, COSV99522324; called by muse, mutect2, varscan2
- ATM | c.172G>A p.D58N | Missense Mutation (SNP) | VAF 39/112 reads (35%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.956); catalogued as COSV99591927; called by muse, mutect2, varscan2
- ATP13A3 | c.2777+1G>A p.X926_splice | Splice Site (SNP) | VAF 4/24 reads (17%) | catalogued as COSV99757650; called by muse, mutect2
- ATP2A1 | c.931C>T p.L311F | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100837404; called by muse, mutect2, varscan2
- ATP2A2 | c.1121G>A p.G374D | Missense Mutation (SNP) | VAF 12/290 reads (4%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as COSV100428895; called by muse, mutect2
- ATP2C2 | c.327+1G>A p.X109_splice | Splice Site (SNP) | VAF 15/42 reads (36%) | catalogued as COSV99298629; called by muse, mutect2, varscan2
- ATP5ME | c.19G>A p.V7I | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV99728387; called by muse, mutect2, varscan2
- ATP6AP2 | c.92G>A p.R31Q | Missense Mutation (SNP) | VAF 42/96 reads (44%) | SIFT tolerated (0.55); PolyPhen benign (0.009); catalogued as rs768989127, COSV65797125; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP6V0A4 | c.2414C>T p.A805V | Missense Mutation (SNP) | VAF 62/282 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100023691; called by muse, varscan2
- ATP6V1E1 | c.442G>A p.V148M | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.626); catalogued as COSV53660085; called by muse, mutect2, varscan2
- ATP9B | c.2815G>A p.G939S | Missense Mutation (SNP) | VAF 16/22 reads (73%) | SIFT tolerated (0.08); PolyPhen benign (0.333); catalogued as COSV100304214, COSV56949248; called by muse, mutect2, varscan2
- ATRN | c.1726G>A p.D576N | Missense Mutation (SNP) | VAF 69/182 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99497837; called by muse, mutect2, varscan2
- ATRN | c.2414C>T p.A805V | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.284); catalogued as COSV99497838; called by muse, mutect2, varscan2
- ATXN7L2 | c.1835G>A p.G612E | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.182); catalogued as COSV100149945; called by muse, mutect2, varscan2
- AURKA | c.44C>A p.A15D | Missense Mutation (SNP) | VAF 37/92 reads (40%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.169); catalogued as COSV100453214; called by muse, mutect2, varscan2
- AVL9 | c.1051G>A p.G351R | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as rs1382170515, COSV100594799; called by muse, mutect2, varscan2
- AVPR1A | c.569C>T p.S190F | Missense Mutation (SNP) | VAF 44/115 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1565878986, COSV100146914; called by muse, mutect2, varscan2
- AXIN2 | c.58G>A p.D20N | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs768267292, COSV100195739; called by muse, mutect2
- AZGP1 | c.802G>A p.V268M | Missense Mutation (SNP) | VAF 6/95 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.194); catalogued as COSV99448219; called by muse, mutect2
- B3GAT1 | c.952G>A p.V318M | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.174); catalogued as COSV100438191; called by muse, mutect2, varscan2
- BAG6 | c.1279G>A p.A427T | Missense Mutation (SNP) | VAF 44/138 reads (32%) | SIFT tolerated (0.29); PolyPhen benign (0.005); catalogued as COSV99277631; called by muse, mutect2, varscan2
- BAIAP3 | c.740G>A p.G247D | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT tolerated (0.24); PolyPhen benign (0.42); catalogued as rs377482883; called by muse, mutect2, varscan2
- BAZ1B | c.757G>A p.V253I | Missense Mutation (SNP) | VAF 18/161 reads (11%) | SIFT tolerated (0.74); PolyPhen benign (0.001); catalogued as COSV100290145; called by muse, mutect2, varscan2
- BCL3 | c.1231C>T p.P411S | Missense Mutation (SNP) | VAF 12/304 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.041); catalogued as COSV51234011; called by muse, mutect2
- BHLHE40 | c.1178C>T p.S393F | Missense Mutation (SNP) | VAF 6/110 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99848295; called by muse, mutect2
- BICRAL | c.1951G>A p.D651N | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT tolerated (0.45); PolyPhen benign (0.079); catalogued as COSV100018481, COSV58404345; called by muse, mutect2, varscan2
- BIRC6 | c.13946G>A p.G4649D | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101428895; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.412C>T p.P138S | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.988); catalogued as COSV99959097; called by muse, mutect2, varscan2
- BMX | c.1106C>T p.S369F | Missense Mutation (SNP) | VAF 43/147 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100564667; called by muse, mutect2, varscan2
- BNC1 | c.1951G>A p.D651N | Missense Mutation (SNP) | VAF 28/109 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV100597483; called by muse, mutect2, varscan2
- BOLL | c.427G>A p.G143S | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV99987429; called by muse, mutect2, varscan2
- BRAT1 | c.584C>T p.A195V | Missense Mutation (SNP) | VAF 13/135 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.144); catalogued as rs1562579622, COSV100500680; called by muse, mutect2, varscan2
- BRD1 | c.1976G>A p.G659E | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99350303; called by muse, mutect2, varscan2
- BRD4 | c.98C>T p.A33V | Missense Mutation (SNP) | VAF 19/129 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.16); catalogued as rs201539391, COSV99651420; called by muse, mutect2, varscan2
- BRPF3 | c.407C>T p.A136V | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.916); catalogued as COSV100326183; called by muse, mutect2, varscan2
- BRPF3 | c.2120G>A p.G707D | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs777424522, COSV100326186; called by muse, mutect2, varscan2
- BRWD3 | c.4886C>T p.S1629F | Missense Mutation (SNP) | VAF 59/176 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.125); catalogued as COSV100956543; called by muse, mutect2, varscan2
- BTAF1 | c.1609G>A p.A537T | Missense Mutation (SNP) | VAF 19/108 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.138); catalogued as COSV99795832; called by muse, mutect2, varscan2
- BTBD3 | c.976G>A p.A326T | Missense Mutation (SNP) | VAF 14/124 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV99655729; called by muse, mutect2, varscan2
- BTN2A1 | c.877G>A p.A293T | Missense Mutation (SNP) | VAF 40/130 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0.014); catalogued as rs369748235, COSV100438791; called by muse, mutect2, varscan2
- BTNL8 | c.707C>T p.A236V | Missense Mutation (SNP) | VAF 124/204 reads (61%) | SIFT tolerated (0.12); PolyPhen benign (0.351); catalogued as COSV99180579; called by muse, mutect2, varscan2
- BUD13 | c.1235G>A p.S412N | Missense Mutation (SNP) | VAF 17/139 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0.011); catalogued as COSV99496752; called by muse, mutect2, varscan2
- BUD13 | c.527C>T p.P176L | Missense Mutation (SNP) | VAF 47/162 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs768661605, COSV99496758; called by muse, mutect2, varscan2
- C1orf162 | c.29C>T p.P10L | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.408); catalogued as COSV100636248; called by muse, mutect2, varscan2
- C22orf31 | c.295G>A p.G99R | Missense Mutation (SNP) | VAF 37/113 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.021); catalogued as COSV99326519; called by muse, mutect2, varscan2
- C2orf15 | c.130A>G p.T44A | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.637); catalogued as rs1237042869, COSV100209101; called by muse, mutect2, varscan2
- C2orf16 | c.745G>A p.G249R | Missense Mutation (SNP) | VAF 45/119 reads (38%) | SIFT tolerated (0.35); PolyPhen benign (0.011); catalogued as COSV101284423; called by muse, mutect2, varscan2
- CA7 | c.763G>A p.G255S | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.487); catalogued as COSV100623817; called by muse, mutect2, varscan2
- CA9 | c.280G>A p.D94N | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.149); catalogued as COSV100999899; called by muse, mutect2, varscan2
- CABLES2 | c.1057C>T p.P353S | Missense Mutation (SNP) | VAF 13/176 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99653301; called by muse, mutect2
- CACNA1A | c.3665C>T p.P1222L | Missense Mutation (SNP) | VAF 7/112 reads (6%) | SIFT tolerated (0.34); PolyPhen benign (0.111); catalogued as COSV100803213; called by muse, mutect2
- CACNA1B | c.2049G>A p.M683I | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.608); catalogued as rs200239452, COSV53121895; called by muse, varscan2
- CACNA1D | c.2713G>A p.A905T (on ENST00000350061 / NM_001128840.3; = p.A925T on NM_000720.4) | Missense Mutation (SNP) | VAF 45/111 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs764701041, COSV99858964; called by muse, mutect2, varscan2
- CACNA1F | c.1255C>T p.P419S | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.54); PolyPhen benign (0.039); catalogued as COSV100545385; called by muse, mutect2, varscan2
- CACNA1I | c.4427C>T p.T1476I | Missense Mutation (SNP) | VAF 43/170 reads (25%) | SIFT tolerated (0.35); PolyPhen benign (0.055); catalogued as COSV100361543; called by muse, mutect2, varscan2
- CAD | c.3814G>A p.A1272T | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.879); catalogued as COSV99255745; called by muse, mutect2, varscan2
- CALCOCO1 | c.742G>A p.E248K | Missense Mutation (SNP) | VAF 10/229 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV100017497; called by muse, mutect2
- CALD1 | c.740G>A p.G247D | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); catalogued as rs777912440, COSV100724572; called by muse, mutect2, varscan2
- CAMSAP2 | c.508G>A p.A170T | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT tolerated (0.37); PolyPhen benign (0.006); catalogued as COSV99374347; called by muse, mutect2, varscan2
- CAND1 | c.833C>T p.A278V | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.173); catalogued as COSV101598292; called by muse, mutect2, varscan2
- CAND1 | c.1948G>A p.E650K | Missense Mutation (SNP) | VAF 43/147 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.176); catalogued as COSV101607356; called by muse, mutect2, varscan2
- CARHSP1 | c.420G>A p.W140* | Nonsense Mutation (SNP) | VAF 18/37 reads (49%) | catalogued as COSV100220272; called by muse, mutect2, varscan2
- CARMIL1 | c.3725G>A p.G1242D | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.046); catalogued as rs373639329; called by muse, mutect2, varscan2
- CARMIL2 | c.631G>A p.A211T | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.868); catalogued as COSV58029605; called by muse, mutect2, varscan2
- CASP8 | c.458G>A p.G153E (on ENST00000432109 / NM_033355.3; = p.G185E on NM_001228.4) | Missense Mutation (SNP) | VAF 53/136 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.14); catalogued as COSV51853138, COSV99965995; called by muse, mutect2, varscan2
- CBFA2T2 | c.1450G>A p.D484N | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.631); catalogued as COSV100656530; called by muse, mutect2, varscan2
- CBLN1 | c.265-1G>A p.X89_splice | Splice Site (SNP) | VAF 17/45 reads (38%) | catalogued as COSV99535809, COSV99535819; called by muse, mutect2, varscan2
- CC2D1A | c.1948C>T p.P650S | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.505); catalogued as rs746894472, COSV100528241, COSV100528704; called by muse, mutect2, varscan2
- CC2D2A | c.2584C>T p.P862S | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101052936; called by muse, mutect2, varscan2
- CCDC115 | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.375); catalogued as COSV52092206, COSV99383855; called by muse, mutect2, varscan2
- CCDC144A | c.1555G>A p.E519K | Missense Mutation (SNP) | VAF 34/144 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.021); catalogued as COSV100138708; called by muse, mutect2, varscan2
- CCDC148 | c.787G>A p.D263N | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.429); catalogued as COSV99321431; called by muse, mutect2, varscan2
- CCDC32 | c.260G>A p.R87K | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT tolerated (0.46); PolyPhen benign (0.015); catalogued as COSV100786014; called by muse, mutect2, varscan2
- CCDC77 | c.583+1G>A p.X195_splice | Splice Site (SNP) | VAF 23/124 reads (19%) | catalogued as COSV99520078; called by muse, mutect2, varscan2
- CCDC93 | c.1142G>A p.S381N | Missense Mutation (SNP) | VAF 48/135 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.014); catalogued as COSV100099491; called by muse, mutect2, varscan2
- CCDC93 | c.145C>T p.P49S | Missense Mutation (SNP) | VAF 11/101 reads (11%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.705); catalogued as COSV60122135; called by muse, mutect2, varscan2
- CCM2 | c.230C>T p.P77L | Missense Mutation (SNP) | VAF 27/115 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.422); catalogued as COSV51850865; called by muse, mutect2, varscan2
- CCNE1 | c.541G>A p.E181K | Missense Mutation (SNP) | VAF 32/89 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as COSV99388638; called by muse, mutect2, varscan2
- CD109 | c.2135C>T p.T712I | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.807); catalogued as COSV99754627; called by muse, mutect2, varscan2
- CD177 | c.383C>T p.P128L | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT tolerated (0.29); PolyPhen benign (0.381); catalogued as COSV100946074; called by muse, mutect2, varscan2
- CD22 | c.2237C>T p.P746L | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.523); catalogued as COSV99323765; called by muse, mutect2, varscan2
- CD59 | c.122C>T p.A41V | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated (0.73); PolyPhen benign (0.001); catalogued as COSV60919887; called by muse, mutect2, varscan2
- CD93 | c.733C>T p.P245S | Missense Mutation (SNP) | VAF 7/140 reads (5%) | SIFT tolerated (0.46); PolyPhen benign (0.009); catalogued as COSV99849587; called by muse, mutect2
- CDC14A | c.1331C>T p.T444I | Missense Mutation (SNP) | VAF 44/119 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0.078); catalogued as COSV100325972; called by muse, mutect2, varscan2
- CDC42EP2 | c.208G>A p.V70M | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.163); catalogued as COSV99659196; called by muse, mutect2, varscan2
- CDCA2 | c.650C>T p.A217V | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.082); catalogued as rs1486521925, COSV100399160; called by muse, mutect2, varscan2
- CDH1 | c.2452G>A p.A818T | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1223994260, COSV99932669; called by muse, mutect2, varscan2
- CDH16 | c.1523G>A p.G508E | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.254); catalogued as rs753329026, COSV100234211; called by muse, mutect2, varscan2
- CDH9 | c.134G>A p.G45D | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs1311387363, COSV50260095; called by muse, mutect2, varscan2
- CDHR1 | c.1956G>A p.W652* | Nonsense Mutation (SNP) | VAF 36/131 reads (27%) | catalogued as COSV60562661; called by muse, mutect2, varscan2
- CDK5RAP2 | c.1933G>A p.V645M | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.618); catalogued as rs1333534849, COSV100575740; called by muse, mutect2, varscan2
- CDKAL1 | c.1465G>A p.G489R | Missense Mutation (SNP) | VAF 35/101 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99216473; called by muse, mutect2, varscan2
- CDKN2AIP | c.341C>T p.T114I | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs551218956, COSV100187734; called by mutect2, varscan2
- CEACAM1 | c.665G>A p.S222N | Missense Mutation (SNP) | VAF 66/194 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.656); catalogued as COSV99362626; called by muse, mutect2, varscan2
- CELSR1 | c.4201G>A p.D1401N | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.98); PolyPhen benign (0.003); catalogued as COSV53101365, COSV99420038; called by muse, mutect2
- CELSR3 | c.8399C>T p.P2800L | Missense Mutation (SNP) | VAF 29/113 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.113); catalogued as COSV99374993; called by muse, mutect2, varscan2
- CELSR3 | c.7583C>T p.P2528L | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.119); catalogued as COSV99375000; called by muse, mutect2, varscan2
- CELSR3 | c.490G>A p.G164S | Missense Mutation (SNP) | VAF 7/145 reads (5%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); catalogued as COSV99375005; called by muse, mutect2
- CENPE | c.964-1G>A p.X322_splice | Splice Site (SNP) | VAF 17/51 reads (33%) | catalogued as COSV54386869, COSV99479167; called by muse, mutect2, varscan2
- CENPF | c.8848C>T p.P2950S | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.251); catalogued as COSV100871971; called by muse, mutect2, varscan2
- CES4A | c.1255G>A p.D419N | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.398); catalogued as rs868001192, COSV100110272; called by muse, mutect2, varscan2
- CFAP43 | c.4192G>A p.A1398T | Missense Mutation (SNP) | VAF 43/122 reads (35%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV100829475; called by muse, mutect2, varscan2
- CFAP47 | c.4565C>A p.S1522Y | Missense Mutation (SNP) | VAF 40/79 reads (51%) | SIFT tolerated (1); PolyPhen benign (0.062); catalogued as COSV57972708; called by muse, mutect2, varscan2
- CFAP53 | c.47C>T p.P16L | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV99497248; called by muse, mutect2, varscan2
- CFAP54 | c.7853G>A p.R2618H | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.52); catalogued as rs1366316096, COSV100733337; called by muse, mutect2, varscan2
- CFAP61 | c.244G>A p.D82N | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT tolerated (0.52); PolyPhen benign (0.025); catalogued as COSV99846654; called by muse, mutect2
- CFTR | c.1693G>A p.D565N | Missense Mutation (SNP) | VAF 72/337 reads (21%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.988); catalogued as COSV50107466, COSV99133859, COSV99139792; called by muse, mutect2, varscan2
- CHAC2 | c.104G>A p.G35D | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.806); catalogued as rs752503321, COSV99712519; called by muse, mutect2, varscan2
- CHAF1B | c.1387C>T p.P463S | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as COSV100023773; called by mutect2, varscan2
- CHCHD5 | c.310G>A p.A104T | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as rs1439638137, COSV100260927; called by muse, mutect2, varscan2
- CHD3 | c.2049C>T p.H683= | Splice Region (SNP) | VAF 34/89 reads (38%) | catalogued as rs1203886087, COSV100391705; called by muse, mutect2, varscan2
- CHD4 | c.4519G>A p.E1507K (on ENST00000357008 / NM_001363606.2; = p.E1520K on NM_001273.5) | Missense Mutation (SNP) | VAF 44/127 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.366); catalogued as rs1225030771, COSV100539240; called by muse, varscan2
- CHI3L2 | c.467C>T p.T156I | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.037); catalogued as COSV63874986; called by muse, mutect2, varscan2
- CHRDL2 | c.608G>A p.S203N | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.021); catalogued as rs1424988641, COSV99734114; called by muse, varscan2
- CHRNB4 | c.182C>T p.S61F | Missense Mutation (SNP) | VAF 33/112 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.756); catalogued as rs1381387028, COSV99929605; called by muse, mutect2, varscan2
- CHRND | c.677C>T p.A226V | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs773215337, COSV99286142; called by muse, mutect2, varscan2
- CHST12 | c.697G>A p.V233I | Missense Mutation (SNP) | VAF 25/99 reads (25%) | SIFT tolerated (0.77); PolyPhen benign (0.007); catalogued as COSV99324680; called by muse, mutect2, varscan2
- CIBAR1 | c.100T>C p.F34L | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.105); catalogued as COSV100844727; called by muse, mutect2
- CIC | c.3404C>T p.P1135L | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as COSV99360284; called by muse, mutect2, varscan2
- CKAP2L | c.668C>T p.P223L | Missense Mutation (SNP) | VAF 45/114 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.066); catalogued as COSV100198777; called by muse, mutect2, varscan2
- CKM | c.364G>A p.D122N | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.758); catalogued as rs1307778519, COSV99675695; called by muse, mutect2, varscan2
- CLDN19 | c.391C>T p.L131F | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.991); catalogued as COSV99591763; called by muse, mutect2, varscan2
- CLEC16A | c.2498C>T p.P833L | Missense Mutation (SNP) | VAF 15/258 reads (6%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as COSV99901760; called by muse, mutect2
- CLIP1 | c.3236C>T p.A1079V (on ENST00000620786 / NM_001247997.1; = p.A1068V on NM_002956.2) | Missense Mutation (SNP) | VAF 41/108 reads (38%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.905); catalogued as COSV100212396; called by muse, mutect2
- CLIP1 | c.578G>A p.S193N | Missense Mutation (SNP) | VAF 79/245 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.768); catalogued as COSV100212398; called by muse, mutect2, varscan2
- CLIP2 | c.1132G>A p.E378K | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99792262; called by muse, mutect2, varscan2
- CLPTM1 | c.1168G>A p.G390S | Missense Mutation (SNP) | VAF 12/246 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100493957; called by muse, mutect2
- CMAS | c.620G>A p.W207* | Nonsense Mutation (SNP) | VAF 55/155 reads (35%) | catalogued as COSV99982741; called by muse, mutect2, varscan2
- CMC4 | c.87G>T p.Q29H | Missense Mutation (SNP) | VAF 42/117 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.588); catalogued as COSV100749938; called by muse, mutect2, varscan2
- CNDP2 | c.456+1G>A p.X152_splice | Splice Site (SNP) | VAF 13/21 reads (62%) | catalogued as COSV100159285; called by muse, mutect2, varscan2
- CNGB3 | c.2045G>A p.G682D | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.266); catalogued as COSV100183066; called by muse, mutect2, varscan2
- CNOT10 | c.1864G>A p.A622T | Missense Mutation (SNP) | VAF 41/98 reads (42%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as COSV100095070; called by muse, mutect2, varscan2
- CNOT2 | c.1285G>A p.D429N | Missense Mutation (SNP) | VAF 34/84 reads (40%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.579); catalogued as COSV99973132; called by muse, mutect2, varscan2
- CNTN3 | c.1919C>T p.S640F | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.179); catalogued as COSV55162661; called by muse, mutect2, varscan2
- CNTNAP2 | c.299C>T p.T100I | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs762630475, COSV100672881; called by muse, mutect2, varscan2
- CNTNAP2 | c.3899G>A p.G1300E | Missense Mutation (SNP) | VAF 33/126 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.346); catalogued as COSV100672883; called by muse, mutect2, varscan2
- COBL | c.1796C>T p.A599V | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT tolerated (0.29); PolyPhen benign (0.062); catalogued as rs1366532256, COSV99474189; called by muse, mutect2, varscan2
- COBLL1 | c.1385C>T p.P462L (on ENST00000392717; = p.P424L on NM_014900.5) | Missense Mutation (SNP) | VAF 52/155 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV99528688; called by muse, mutect2, varscan2
- COG1 | c.2588G>A p.S863N | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.663); catalogued as COSV100245450; called by muse, mutect2, varscan2
- COL19A1 | c.2393G>A p.G798D | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1210497312, COSV100507527; called by muse, mutect2, varscan2
- COL1A2 | c.3721A>G p.N1241D | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.949); catalogued as COSV99801106; called by muse, mutect2, varscan2
- COL20A1 | c.3659C>T p.P1220L | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1422643636, COSV100491443; called by muse, mutect2, varscan2
- COL22A1 | c.1460G>A p.G487E | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.638); catalogued as rs267601793, COSV100278526; called by muse, mutect2, varscan2
- COL25A1 | c.62C>T p.T21I | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as rs1257092230, COSV101211648; called by muse, mutect2
- COL26A1 | c.277G>A p.V93I | Missense Mutation (SNP) | VAF 38/96 reads (40%) | SIFT tolerated (0.74); PolyPhen benign (0.313); catalogued as rs563017448, COSV58122237, COSV58129698; called by muse, mutect2, varscan2
- COL26A1 | c.278T>A p.V93E | Missense Mutation (SNP) | VAF 36/94 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV100562051; called by muse, mutect2, varscan2
- COL4A3 | c.4393G>A p.V1465M | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as COSV101170536; called by muse, mutect2, varscan2
- COL4A4 | c.194G>A p.G65D | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100307722; called by muse, mutect2, varscan2
- COL4A6 | c.4073-1G>A p.X1358_splice | Splice Site (SNP) | VAF 19/122 reads (16%) | catalogued as COSV100565037; called by muse, mutect2, varscan2
- COL4A6 | c.3280+1G>A p.X1094_splice | Splice Site (SNP) | VAF 35/66 reads (53%) | catalogued as COSV100565038; called by muse, mutect2, varscan2
- COL5A1 | c.2350G>A p.G784S | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs767627080, COSV100880585; called by muse, varscan2
- COL5A1 | c.2953G>A p.G985S | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65664725, COSV65666338; called by muse, mutect2, varscan2
- COL5A2 | c.2509G>A p.G837S | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs780353849, COSV100880812; called by muse, mutect2, varscan2
- COL5A3 | c.2912G>A p.G971E | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1469321485, COSV99319776; called by muse, mutect2, varscan2
- COL8A1 | c.352G>A p.G118R | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99658505; called by muse, mutect2
- CPA5 | c.1303C>T p.P435S | Missense Mutation (SNP) | VAF 24/122 reads (20%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.803); catalogued as rs1359557265, COSV100812476; called by muse, mutect2, varscan2
- CPB2 | c.350C>T p.A117V | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.019); catalogued as COSV99473292; called by muse, mutect2, varscan2
- CPD | c.1510C>T p.H504Y | Missense Mutation (SNP) | VAF 31/165 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99853291; called by muse, mutect2, varscan2
- CPLANE2 | c.496C>T p.P166S | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT tolerated (0.42); PolyPhen benign (0.179); catalogued as rs773850912, COSV100983288; called by muse, mutect2, varscan2
- CPNE9 | c.546G>A p.T182= | Splice Region (SNP) | VAF 12/38 reads (32%) | catalogued as COSV99808473; called by muse, mutect2, varscan2
- CPS1 | c.1568G>A p.R523K | Missense Mutation (SNP) | VAF 31/111 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.031); catalogued as COSV99244075; called by muse, mutect2, varscan2
- CPT2 | c.992C>T p.P331L | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT tolerated (0.25); PolyPhen benign (0.009); catalogued as COSV99598340; called by muse, mutect2, varscan2
- CRB2 | c.764G>A p.G255D | Missense Mutation (SNP) | VAF 11/136 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100749740; called by muse, mutect2
- CRYBG1 | c.3424C>T p.P1142S | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1214570956, COSV100954624; called by muse, mutect2, varscan2
- CRYBG3 | c.5843C>T p.A1948V | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.165); catalogued as COSV99477495; called by muse, mutect2, varscan2
- CSF2 | c.332C>T p.T111I | Missense Mutation (SNP) | VAF 6/144 reads (4%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.93); catalogued as COSV51522852; called by muse, mutect2
- CSKMT | c.58C>T p.P20S | Missense Mutation (SNP) | VAF 5/65 reads (8%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.003); catalogued as COSV100649283; called by muse, mutect2
- CSMD1 | c.3151G>A p.V1051I (on ENST00000520002; = p.V1050I on NM_033225.6) | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.986); catalogued as rs1397943447, COSV100153734; called by muse, mutect2, varscan2
- CSMD2 | c.2300G>A p.G767D | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1411334338, COSV99592303; called by muse, mutect2, varscan2
- CSNK1G3 | c.991C>T p.P331S | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT tolerated (0.32); PolyPhen benign (0.026); catalogued as COSV100631791; called by muse, mutect2, varscan2
- CSPP1 | c.1077G>A p.M359I (on ENST00000676605; = p.M318I on NM_024790.6) | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT tolerated (0.45); PolyPhen benign (0.03); catalogued as rs1264364769, COSV99139913; called by muse, mutect2, varscan2
- CSRNP2 | c.1090C>T p.P364S | Missense Mutation (SNP) | VAF 45/109 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.548); catalogued as rs779718346, COSV50397922; called by muse, mutect2, varscan2
- CST9 | c.379G>A p.G127S | Missense Mutation (SNP) | VAF 39/108 reads (36%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as rs1306313946, COSV100980498; called by muse, mutect2, varscan2
- CSTF1 | c.1037G>A p.G346D | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99410353; called by muse, mutect2, varscan2
- CTAGE1 | c.1933C>T p.P645S | Missense Mutation (SNP) | VAF 70/244 reads (29%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.975); catalogued as rs1444024437, COSV101194680; called by muse, mutect2, varscan2
- CTNNA1 | c.1472G>A p.W491* | Nonsense Mutation (SNP) | VAF 20/314 reads (6%) | catalogued as rs749135177, COSV100243255; called by muse, mutect2
- CTNND2 | c.2173G>A p.A725T | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.902); catalogued as rs771925503, COSV100481074; called by muse, mutect2, varscan2
- CTSE | c.1195G>A p.A399T (on ENST00000360218; = p.A394T on NM_001910.4) | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.479); catalogued as COSV100733754; called by muse, mutect2, varscan2
- CUX1 | c.3509C>T p.P1170L | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52909968; called by muse, mutect2, varscan2
- CXCL5 | c.322G>A p.D108N | Missense Mutation (SNP) | VAF 11/125 reads (9%) | SIFT tolerated (0.55); PolyPhen benign (0.145); catalogued as COSV99932949; called by muse, mutect2
- CXCR3 | c.806C>T p.T269I | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV101031741; called by muse, mutect2, varscan2
- CYBC1 | c.439C>T p.R147C | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs150870793; called by muse, mutect2, varscan2
- CYP1A1 | c.515G>A p.S172N | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as COSV101122381; called by muse, mutect2, varscan2
- CYP26B1 | c.1309G>A p.G437S | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1228321015, COSV50011655; called by muse, mutect2, varscan2
- CYP2C18 | c.25C>T p.L9F | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT tolerated (0.24); PolyPhen benign (0.109); catalogued as COSV99608996; called by muse, mutect2, varscan2
- CYP2C18 | c.1466C>T p.P489L | Missense Mutation (SNP) | VAF 17/103 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99609002; called by muse, varscan2
- CYP2S1 | c.976+1G>A p.X326_splice | Splice Site (SNP) | VAF 13/129 reads (10%) | catalogued as COSV100027600; called by muse, mutect2, varscan2
- CYP2W1 | c.1150C>T p.P384S | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.474); catalogued as COSV100417322; called by muse, mutect2, varscan2
- CYP4Z1 | c.808G>A p.D270N | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT tolerated (0.52); PolyPhen benign (0.018); catalogued as COSV100497928; called by muse, mutect2, varscan2
- DAAM1 | c.2664C>T p.N888= | Splice Region (SNP) | VAF 9/66 reads (14%) | catalogued as rs1481026082, COSV100658664; called by muse, mutect2, varscan2
- DBF4 | c.399+1G>A p.X133_splice | Splice Site (SNP) | VAF 18/109 reads (17%) | catalogued as COSV99719584; called by muse, mutect2, varscan2
- DBF4 | c.1462G>A p.A488T | Missense Mutation (SNP) | VAF 29/118 reads (25%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as COSV99719585; called by muse, mutect2, varscan2
- DCAF12L2 | c.209G>A p.G70D | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs1016983776, COSV100758849; called by muse, mutect2, varscan2
- DCAF7 | c.897G>A p.M299I | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.21); PolyPhen benign (0.009); catalogued as COSV100177763; called by muse, mutect2, varscan2
- DCC | c.2758G>A p.V920I | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as COSV100503107; called by muse, mutect2, varscan2
- DCLRE1C | c.442G>A p.E148K (on ENST00000378278 / NM_001350965.2; = p.E33K on NM_022487.4) | Missense Mutation (SNP) | VAF 13/332 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.212); catalogued as rs1194135971, COSV63182918; called by muse, mutect2
- DCST1 | c.968C>T p.S323F | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV55057558, COSV99793644; called by muse, mutect2
- DCSTAMP | c.601G>A p.A201T | Missense Mutation (SNP) | VAF 11/138 reads (8%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV99886964; called by muse, mutect2
- DCT | c.145G>A p.A49T | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs748563244, COSV100986309; called by muse, mutect2, varscan2
- DCTN4 | c.502G>A p.A168T | Missense Mutation (SNP) | VAF 15/121 reads (12%) | SIFT tolerated (0.74); PolyPhen benign (0.005); catalogued as COSV101437586; called by muse, mutect2, varscan2
- DDX17 | c.1810G>A p.D604N | Missense Mutation (SNP) | VAF 34/109 reads (31%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.006); catalogued as COSV99318366; called by muse, mutect2, varscan2
- DDX20 | c.1099G>A p.D367N | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100865965; called by muse, mutect2, varscan2
- DDX24 | c.2312G>A p.G771E | Missense Mutation (SNP) | VAF 27/136 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.051); catalogued as COSV99180226; called by muse, mutect2, varscan2
- DDX28 | c.1340C>T p.S447F | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.091); catalogued as COSV100193152; called by muse, mutect2
- DDX42 | c.1399G>A p.A467T | Missense Mutation (SNP) | VAF 131/436 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100835078; called by muse, mutect2, varscan2
- DDX5 | c.647G>A p.R216K | Missense Mutation (SNP) | VAF 6/112 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.3); catalogued as rs1555671467, COSV99858274; called by muse, mutect2
- DDX50 | c.1493G>A p.G498D | Missense Mutation (SNP) | VAF 44/124 reads (35%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV101007311; called by muse, mutect2, varscan2
- DDX51 | c.1694C>T p.T565I | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as COSV100223208; called by muse, mutect2, varscan2
- DENND4A | c.139G>A p.D47N | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101475435; called by muse, mutect2, varscan2
- DEPDC5 | c.1919C>T p.S640F (on ENST00000400246; = p.S718F on NM_014662.5) | Missense Mutation (SNP) | VAF 92/319 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.708); catalogued as COSV99836569; called by muse, mutect2, varscan2
- DGKA | c.1738G>A p.V580I | Missense Mutation (SNP) | VAF 35/86 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.047); catalogued as rs1223022588, COSV100093453; called by muse, mutect2, varscan2
- DGKG | c.1261G>A p.V421I | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV99404385; called by muse, mutect2, varscan2
- DGLUCY | c.269C>T p.P90L | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT tolerated (0.46); PolyPhen benign (0.018); catalogued as COSV99824746; called by muse, mutect2, varscan2
- DHRSX | c.299A>G p.Y100C | Missense Mutation (SNP) | VAF 52/143 reads (36%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.943); catalogued as COSV100586070; called by muse, mutect2, varscan2
- DHX29 | c.3391G>A p.A1131T | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.725); catalogued as rs566797481, COSV52416622; called by muse, mutect2, varscan2
- DHX37 | c.85C>T p.P29S | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs1212516440, COSV100413178; called by muse, mutect2, varscan2
- DHX57 | c.2432G>A p.S811N | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.039); catalogued as rs779759078, COSV99769954; called by muse, mutect2, varscan2
- DHX9 | c.3760G>A p.G1254R | Missense Mutation (SNP) | VAF 11/15 reads (73%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV100841521; called by muse, mutect2, varscan2
- DIP2C | c.4091G>A p.G1364E | Missense Mutation (SNP) | VAF 54/257 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99793761; called by muse, mutect2, varscan2
- DIP2C | c.977G>A p.R326K | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.115); catalogued as COSV99793763; called by muse, mutect2
- DIP2C | c.562G>A p.A188T | Missense Mutation (SNP) | VAF 7/109 reads (6%) | SIFT tolerated (0.54); PolyPhen benign (0.045); catalogued as rs1564693527, COSV55185947; called by muse, mutect2
- DIPK2A | c.887G>A p.G296D | Missense Mutation (SNP) | VAF 47/79 reads (59%) | SIFT tolerated (1); PolyPhen probably damaging (0.996); catalogued as COSV100237458; called by muse, mutect2, varscan2
- DLGAP5 | c.2159C>T p.S720F | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.235); catalogued as COSV99904154; called by muse, mutect2, varscan2
- DLL1 | c.656C>T p.P219L | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV100816193; called by muse, mutect2, varscan2
- DLL3 | c.736C>T p.P246S | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as COSV99219519; called by muse, mutect2, varscan2
- DLX5 | c.88C>T p.P30S | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.576); catalogued as COSV99756686; called by muse, mutect2, varscan2
- DMXL2 | c.5041G>A p.G1681S | Missense Mutation (SNP) | VAF 33/100 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1421440122, COSV99198598; called by muse, mutect2, varscan2
- DNAH11 | c.4625C>T p.T1542I | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as rs953927007, COSV100180880; called by muse, mutect2, varscan2
- DNAH11 | c.6822G>A p.M2274I | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100180881; called by muse, mutect2
- DNAH11 | c.8522G>A p.S2841N | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.067); catalogued as rs1209635792, COSV100180882; called by muse, mutect2, varscan2
- DNAH7 | c.486+1G>A p.X162_splice | Splice Site (SNP) | VAF 16/142 reads (11%) | catalogued as rs1378307109, COSV100417570; called by muse, mutect2, varscan2
- DNAH8 | c.7460C>T p.S2487F | Missense Mutation (SNP) | VAF 52/122 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs751647473, COSV100547239; called by muse, mutect2, varscan2
- DNAJC11 | c.293G>A p.R98K | Missense Mutation (SNP) | VAF 22/35 reads (63%) | SIFT tolerated (0.92); PolyPhen benign (0.067); catalogued as COSV99602628; called by muse, varscan2
- DNAJC14 | c.1076G>A p.R359K | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as rs1430107346, COSV100423733; called by muse, mutect2, varscan2
- DNAJC14 | c.92C>T p.P31L | Missense Mutation (SNP) | VAF 11/113 reads (10%) | SIFT tolerated, low confidence (0.17); PolyPhen probably damaging (0.996); catalogued as COSV100423734; called by muse, mutect2
- DNAJC22 | c.253G>A p.V85M | Missense Mutation (SNP) | VAF 9/189 reads (5%) | SIFT tolerated (0.77); PolyPhen benign (0.001); catalogued as COSV101222605; called by muse, mutect2
- DNAJC25 | c.755C>T p.A252V | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT tolerated (0.31); PolyPhen benign (0.122); catalogued as COSV100543455; called by muse, mutect2, varscan2
- DNASE1L1 | c.262C>T p.P88S | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT tolerated (0.74); PolyPhen benign (0.026); catalogued as COSV99186323; called by muse, mutect2, varscan2
- DNM2 | c.577G>A p.V193I | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.889); catalogued as COSV100118007; called by muse, mutect2, varscan2
- DNMBP | c.4730C>T p.T1577I | Missense Mutation (SNP) | VAF 34/91 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1292712041, COSV100144436; called by muse, mutect2, varscan2
- DNMT1 | c.3383G>A p.S1128N | Missense Mutation (SNP) | VAF 38/87 reads (44%) | SIFT tolerated (0.26); PolyPhen benign (0.011); catalogued as COSV100533065; called by muse, mutect2, varscan2
- DNMT3B | c.205G>A p.D69N | Missense Mutation (SNP) | VAF 6/65 reads (9%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.075); catalogued as rs894023534, COSV99144155; called by muse, mutect2
- DNMT3B | c.1016G>A p.G339D | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs754921958, COSV99144170; called by muse, mutect2, varscan2
- DOCK10 | c.3254C>T p.S1085F | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.352); catalogued as COSV51417531; called by muse, mutect2, varscan2
- DPF2 | c.346G>A p.G116S | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT tolerated (0.18); PolyPhen benign (0.03); catalogued as COSV99361954; called by muse, mutect2, varscan2
- DPH7 | c.1204G>A p.G402S | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as rs1210300054, COSV99483697; called by muse, mutect2, varscan2
- DPYSL3 | c.832C>T p.P278S | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.949); catalogued as COSV100575391, COSV58325497; called by muse, mutect2, varscan2
- DRC7 | c.1271C>T p.S424F | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as rs1416752582; called by muse, mutect2
- DSG1 | c.1187G>A p.G396D | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV99936582; called by muse, mutect2, varscan2
- DUOX1 | c.4595C>T p.A1532V | Missense Mutation (SNP) | VAF 55/172 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV99334806; called by muse, mutect2, varscan2
- DUSP4 | c.463C>T p.P155S | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.178); catalogued as COSV99530063; called by muse, mutect2
- DUT | c.286C>T p.P96S (on ENST00000331200 / NM_001025248.2; = p.P8S on NM_001948.4) | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.02); catalogued as rs766999002, COSV100485332; called by muse, varscan2
- DYDC1 | c.412G>A p.D138N | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.081); catalogued as rs753801957, COSV100943870, COSV64732228; called by muse, mutect2, varscan2
- DYNC1H1 | c.2690C>T p.P897L | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (0.25); PolyPhen benign (0.05); catalogued as COSV100795392; called by muse, mutect2, varscan2
- DYNC1H1 | c.11777G>A p.G3926D | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.055); catalogued as COSV100795393; called by muse, mutect2, varscan2
- DYRK1B | c.1553G>A p.G518E | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.59); catalogued as COSV100546746; called by muse, mutect2, varscan2
- E2F4 | c.1010C>T p.P337L | Missense Mutation (SNP) | VAF 36/153 reads (24%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.996); catalogued as COSV100681966; called by muse, mutect2, varscan2
- ECT2L | c.2377C>T p.L793F | Missense Mutation (SNP) | VAF 37/137 reads (27%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); catalogued as rs1367636984, COSV100872190; called by muse, mutect2, varscan2
- EDEM3 | c.548C>T p.A183V | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100545674; called by muse, mutect2, varscan2
- EEF2K | c.1897G>A p.D633N | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV53780701, COSV99533678; called by muse, mutect2, varscan2
- EEFSEC | c.317G>A p.G106E | Missense Mutation (SNP) | VAF 16/246 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99631404; called by muse, mutect2
- EEPD1 | c.554C>T p.A185V | Missense Mutation (SNP) | VAF 21/112 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.339); catalogued as rs202070535, COSV99633061; called by muse, mutect2, varscan2
- EFL1 | c.14G>A p.S5N | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.012); catalogued as COSV99188673; called by muse, mutect2, varscan2
- EGFR | c.2509G>A p.D837N | Missense Mutation (SNP) | VAF 35/128 reads (27%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.872); catalogued as rs761920220, COSV51859563; called by muse, mutect2, varscan2
- EHBP1 | c.3295C>T p.L1099F | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99860589; called by muse, mutect2, varscan2
- EHBP1L1 | c.1372C>T p.P458S | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.863); catalogued as COSV100500029; called by muse, mutect2, varscan2
- EHD1 | c.1498G>A p.E500K | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100277281; called by muse, mutect2, varscan2
- EIF2AK2 | c.170G>A p.G57D | Missense Mutation (SNP) | VAF 30/64 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1274669139, COSV99241005; called by muse, mutect2, varscan2
- EIF3K | c.500-1G>A p.X167_splice | Splice Site (SNP) | VAF 5/47 reads (11%) | catalogued as COSV50264233; called by muse, mutect2
- ELMO1 | c.2063C>T p.T688I | Missense Mutation (SNP) | VAF 36/124 reads (29%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.544); catalogued as COSV100166012, COSV60302078; called by muse, mutect2, varscan2
- ELN | c.1630G>A p.A544T | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.993); catalogued as COSV99333141; called by muse, mutect2
- ELOVL2 | c.133T>C p.Y45H | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100676087; called by muse, mutect2
- ELP5 | c.94+1G>A p.X32_splice | Splice Site (SNP) | VAF 5/15 reads (33%) | catalogued as COSV100021163; called by muse, mutect2, varscan2
- EMC3 | c.434C>T p.T145I | Missense Mutation (SNP) | VAF 32/92 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99794073; called by muse, mutect2, varscan2
- EMD | c.373C>T p.P125S | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100877375, COSV100877419; called by muse, mutect2, varscan2
- ENG | c.1163C>T p.T388I | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV100785345; called by muse, mutect2, varscan2
- ENOPH1 | c.602G>A p.G201E | Missense Mutation (SNP) | VAF 9/116 reads (8%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.904); catalogued as COSV99908823; called by muse, mutect2
- ENOSF1 | c.442C>T p.Q148* (on ENST00000340116 / NM_001354066.2; = p.Q100* on NM_017512.7 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 19/350 reads (5%) | catalogued as COSV99201167; called by muse, mutect2
- ENOX2 | c.665C>T p.A222V (on ENST00000338144 / NM_001382520.1; = p.A193V on NM_006375.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.917); catalogued as COSV57654905; called by muse, mutect2, varscan2
- ENPP3 | c.1870C>T p.L624F | Missense Mutation (SNP) | VAF 36/111 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.366); catalogued as COSV100718086; called by muse, mutect2, varscan2
- EPB41L4A | c.855G>A p.W285* | Nonsense Mutation (SNP) | VAF 41/95 reads (43%) | catalogued as COSV54881370; called by muse, mutect2, varscan2
- EPB41L4B | c.484G>A p.V162I | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT tolerated (0.26); PolyPhen benign (0.361); catalogued as COSV101000588; called by muse, mutect2, varscan2
- EPG5 | c.197C>T p.S66F | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.157); catalogued as COSV99958119; called by muse, mutect2, varscan2
- EPHA1 | c.2654C>T p.A885V | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV51969801; called by muse, mutect2, varscan2
- EPHA2 | c.2562G>A p.W854* | Nonsense Mutation (SNP) | VAF 22/57 reads (39%) | catalogued as COSV100626294; called by muse, mutect2, varscan2
- EPHA2 | c.1771C>T p.P591S | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100626295; called by muse, mutect2, varscan2
- EPHA8 | c.2081C>T p.P694L | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99385169, COSV99385716; called by muse, mutect2, varscan2
- EPHB6 | c.656C>T p.A219V | Missense Mutation (SNP) | VAF 43/194 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as rs1396467933, COSV67417549, COSV67421566; called by muse, varscan2
- EPHX2 | c.134G>A p.G45E | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.783); catalogued as COSV100994820; called by muse, mutect2, varscan2
- EPOR | c.252G>A p.E84= | Splice Region (SNP) | VAF 5/27 reads (19%) | catalogued as COSV99710311; called by muse, mutect2
- ERBIN | c.3844G>A p.A1282T (on ENST00000284037 / NM_001253697.2; = p.A1241T on NM_018695.4) | Missense Mutation (SNP) | VAF 7/92 reads (8%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.782); catalogued as COSV99397811; called by muse, mutect2
- ERCC2 | c.2131G>A p.D711N | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs763610846, COSV101228937, COSV67269723; called by muse, mutect2, varscan2
- ERCC4 | c.2666G>A p.G889E | Missense Mutation (SNP) | VAF 20/115 reads (17%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.642); catalogued as COSV100319118; called by muse, mutect2, varscan2
- ERCC6 | c.2382+1G>A p.X794_splice | Splice Site (SNP) | VAF 5/38 reads (13%) | catalogued as rs769480050, COSV100876213; called by muse, mutect2, varscan2
- ERCC6L | c.2906G>A p.S969N | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV100559261; called by muse, mutect2, varscan2
- ERF | c.454G>A p.V152M | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.146); catalogued as COSV55896586; called by muse, mutect2, varscan2
- ERI3 | c.226G>A p.G76R | Missense Mutation (SNP) | VAF 39/150 reads (26%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); catalogued as COSV100952261; called by muse, mutect2, varscan2
- ERICH3 | c.3521G>A p.R1174K | Missense Mutation (SNP) | VAF 14/150 reads (9%) | SIFT tolerated (0.31); PolyPhen benign (0.015); catalogued as COSV100445800; called by muse, mutect2
- ESYT1 | c.567G>A p.K189= | Splice Region (SNP) | VAF 27/71 reads (38%) | catalogued as COSV99920303; called by muse, mutect2, varscan2
- ETS2 | c.728G>A p.R243Q | Missense Mutation (SNP) | VAF 12/318 reads (4%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as rs1024159376, COSV62873290; called by muse, mutect2
- ETV3L | c.884G>A p.G295D | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.019); catalogued as COSV101485615; called by muse, mutect2, varscan2
- ETV6 | c.55C>T p.P19S | Missense Mutation (SNP) | VAF 34/108 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV101122478; called by muse, mutect2, varscan2
- EVI2A | c.530C>T p.P177L | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99907714; called by muse, mutect2, varscan2
- EWSR1 | c.941G>A p.R314K | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV100132097; called by muse, mutect2
- EXOSC10 | c.398G>A p.G133D | Missense Mutation (SNP) | VAF 4/49 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100442925; called by muse, mutect2
- EXTL2 | c.532G>A p.V178I | Missense Mutation (SNP) | VAF 40/150 reads (27%) | SIFT tolerated (0.42); PolyPhen benign (0.029); catalogued as rs749120908, COSV100921142; called by muse, mutect2, varscan2
- EYA2 | c.290C>T p.P97L | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV57945339; called by muse, mutect2, varscan2
- F2 | c.631G>A p.E211K | Missense Mutation (SNP) | VAF 35/89 reads (39%) | SIFT tolerated (0.16); PolyPhen benign (0.014); catalogued as COSV61315753; called by muse, mutect2, varscan2
- F5 | c.5237G>A p.G1746D | Missense Mutation (SNP) | VAF 30/145 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100889245; called by muse, mutect2, varscan2
- F9 | c.971C>T p.P324L | Missense Mutation (SNP) | VAF 40/131 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1225527981, CM045764, COSV99496893; called by muse, mutect2, varscan2
- FAM135B | c.670G>A p.G224R | Missense Mutation (SNP) | VAF 18/22 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99424364, COSV99425336; called by muse, mutect2, varscan2
- FAM155B | c.971C>T p.P324L | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99368678; called by muse, mutect2, varscan2
- FAM161B | c.1708C>T p.H570Y (on ENST00000651776; = p.H507Y on NM_152445.3) | Missense Mutation (SNP) | VAF 13/190 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV99679995; called by muse, mutect2
- FAM168B | c.439G>A p.G147S | Missense Mutation (SNP) | VAF 9/106 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs1255512590, COSV101112264; called by muse, mutect2
- FAM171A1 | c.2413G>A p.V805I | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT tolerated (0.23); PolyPhen benign (0.258); catalogued as COSV100968499; called by muse, mutect2, varscan2
- FAM172A | c.742C>T p.R248C | Missense Mutation (SNP) | VAF 59/122 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as rs747628491, COSV67942389; called by muse, mutect2, varscan2
- FAM189A2 | c.214C>T p.P72S | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT tolerated (0.51); PolyPhen probably damaging (0.96); catalogued as COSV99975382; called by muse, mutect2, varscan2
- FAM47A | c.2279G>A p.R760K | Missense Mutation (SNP) | VAF 67/160 reads (42%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as COSV100650084, COSV60499228; called by muse, mutect2, varscan2
- FAM83C | c.520G>A p.A174T | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100981712; called by muse, mutect2, varscan2
- FANCD2OS | c.218C>T p.P73L | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.235); catalogued as rs1242104788, COSV99812500; called by muse, mutect2, varscan2
- FANCM | c.2480C>T p.S827F | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs1165703501, COSV57504644, COSV99951640; called by muse, mutect2, varscan2
- FARSA | c.1519G>A p.A507T | Missense Mutation (SNP) | VAF 35/112 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV99536171; called by muse, mutect2, varscan2
- FBH1 | c.496G>A p.A166T (on ENST00000362091 / NM_178150.3; = p.A217T on NM_032807.4) | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.62); PolyPhen benign (0.006); catalogued as COSV100758943; called by muse, mutect2, varscan2
- FBL | c.452G>A p.G151D | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV55682449, COSV99695429; called by muse, mutect2, varscan2
- FBLN1 | c.1321+1G>A p.X441_splice | Splice Site (SNP) | VAF 12/24 reads (50%) | catalogued as rs113497852, COSV99411470; called by muse, varscan2
- FBLN2 | c.2155G>A p.D719N | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99852655; called by muse, mutect2, varscan2
- FBN1 | c.2677+1G>A p.X893_splice | Splice Site (SNP) | VAF 24/64 reads (38%) | catalogued as COSV100356409; called by muse, mutect2, varscan2
- FBXL13 | c.71C>T p.T24I | Missense Mutation (SNP) | VAF 22/111 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs1262803404, COSV100502115, COSV57535403; called by muse, mutect2, varscan2
- FBXL4 | c.622G>A p.E208K | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV57749093; called by muse, mutect2
- FBXO24 | c.959G>A p.G320E (on ENST00000241071 / NM_033506.3; = p.G358E on NM_012172.5) | Missense Mutation (SNP) | VAF 31/103 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53823974; called by muse, mutect2, varscan2
- FBXO46 | c.347G>A p.S116N | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.782); catalogued as rs1410312448, COSV100480422; called by muse, mutect2, varscan2
- FBXW7 | c.524G>A p.G175D (on ENST00000281708 / NM_001349798.2; = p.G95D on NM_018315.5) | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.409); catalogued as rs1450093163, COSV99660988; called by muse, mutect2, varscan2
- FCGBP | c.12565C>T p.P4189S | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated, low confidence (0.82); PolyPhen benign (0.018); catalogued as rs757614260; called by muse, mutect2
- FCGBP | c.10312G>A p.A3438T | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT tolerated (0.66); PolyPhen benign (0.006); catalogued as rs1429477393; called by muse, mutect2, varscan2
- FCGR2B | c.218G>A p.G73E | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52682694, COSV99375400; called by muse, mutect2, varscan2
- FCGR3B | c.61+1G>A p.X21_splice | Splice Site (SNP) | VAF 5/52 reads (10%) | catalogued as COSV54210615; called by muse, mutect2
- FCRL3 | c.1175C>T p.A392V | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.098); catalogued as rs774313926, COSV100943546, COSV63843555; called by muse, mutect2, varscan2
- FEM1A | c.1714G>A p.A572T | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99521567; called by muse, mutect2, varscan2
- FEM1C | c.1045G>A p.A349T | Missense Mutation (SNP) | VAF 48/123 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1332294657, COSV99174425; called by muse, mutect2, varscan2
- FER1L6 | c.3215G>A p.G1072E | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67552781, COSV99065082; called by muse, mutect2, varscan2
- FERMT3 | c.1661G>A p.G554D (on ENST00000279227 / NM_178443.3; = p.G550D on NM_031471.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1405538743, COSV99656818; called by muse, mutect2, varscan2
- FEZF2 | c.110C>T p.A37V | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.305); catalogued as rs1324909736, COSV51863490; called by muse, varscan2
- FGA | c.1891G>A p.D631N | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.432); catalogued as rs1201472249, COSV100120740; called by muse, mutect2, varscan2
- FHDC1 | c.1993C>T p.P665S | Missense Mutation (SNP) | VAF 17/27 reads (63%) | SIFT tolerated (0.19); PolyPhen benign (0.022); catalogued as rs777076315, COSV99471706; called by muse, mutect2, varscan2
- FKBP9 | c.1678C>T p.L560F | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99640444; called by muse, varscan2
- FLCN | c.1093G>A p.A365T | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.042); catalogued as rs1223326792; called by muse, mutect2
- FLG2 | c.5090G>A p.G1697E | Missense Mutation (SNP) | VAF 111/385 reads (29%) | SIFT tolerated (0.38); PolyPhen benign (0.057); catalogued as COSV66167408; called by muse, mutect2, varscan2
- FLNC | c.6178G>A p.A2060T | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.129); catalogued as COSV100368736; called by muse, mutect2, varscan2
- FLOT1 | c.37G>A p.V13I | Missense Mutation (SNP) | VAF 13/148 reads (9%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.498); catalogued as COSV99458346; called by muse, mutect2
- FLT1 | c.2419G>A p.D807N | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV56724386; called by muse, mutect2, varscan2
- FMNL3 | c.3056G>A p.G1019D | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated, low confidence (0.94); PolyPhen benign (0); catalogued as rs865776352, COSV99526990; called by muse, mutect2, varscan2
- FMO3 | c.817C>T p.P273S | Missense Mutation (SNP) | VAF 29/92 reads (32%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.58); catalogued as COSV100882554; called by muse, mutect2, varscan2
- FN1 | c.6335G>A p.G2112E (on ENST00000359671 / NM_001365524.2; = p.G2081E on NM_002026.4) | Missense Mutation (SNP) | VAF 6/108 reads (6%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.799); catalogued as COSV100118275; called by muse, mutect2
- FN1 | c.802T>A p.W268R | Missense Mutation (SNP) | VAF 40/94 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100118280; called by muse, mutect2, varscan2
- FN1 | c.122C>T p.S41F | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated (0.7); PolyPhen benign (0.275); catalogued as COSV100118282; called by muse, mutect2
- FNDC1 | c.5359G>A p.V1787M | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51934963; called by muse, mutect2, varscan2
- FOXA1 | c.1402G>T p.V468F | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); catalogued as COSV99163826; called by muse, mutect2, varscan2
- FOXD4L1 | c.655C>T p.P219S | Missense Mutation (SNP) | VAF 46/153 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); catalogued as rs1217289380, COSV99380821; called by muse, mutect2, varscan2
- FOXH1 | c.187G>A p.V63I | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated (0.69); PolyPhen benign (0.083); catalogued as rs899189505, COSV56762757; called by muse, mutect2, varscan2
- FOXL1 | c.101C>T p.P34L | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.663); catalogued as COSV100206425; called by muse, mutect2, varscan2
- FOXS1 | c.734G>A p.G245E | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as COSV99640217; called by muse, mutect2, varscan2
- FPGS | c.706G>A p.V236M | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.36); PolyPhen benign (0.041); catalogued as COSV100948903; called by muse, mutect2, varscan2
- FRAS1 | c.6899C>T p.T2300I | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV99355820; called by muse, mutect2, varscan2
- FREM1 | c.4751G>A p.G1584E | Missense Mutation (SNP) | VAF 35/193 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as COSV101085486; called by muse, mutect2, varscan2
- FTO | c.1157G>A p.G386D | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67111512; called by muse, mutect2, varscan2
- FTSJ3 | c.2500G>A p.A834T | Missense Mutation (SNP) | VAF 18/264 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.626); catalogued as COSV100835079; called by muse, mutect2
- FTSJ3 | c.110G>A p.R37H | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV100037458; called by muse, mutect2, varscan2
- FUBP3 | c.1591G>A p.A531T | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs773816008, COSV100156320; called by muse, mutect2, varscan2
- FUT1 | c.494C>T p.S165F | Missense Mutation (SNP) | VAF 16/216 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.026); catalogued as rs1027195528, COSV100038272; called by muse, mutect2
- FZD10 | c.448G>A p.A150T | Missense Mutation (SNP) | VAF 19/181 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.933); catalogued as COSV99969603; called by muse, mutect2, varscan2
- G3BP2 | c.1342G>A p.D448N | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.971); catalogued as COSV100693015; called by muse, mutect2
- G6PC | c.611C>T p.A204V | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.156); catalogued as rs969519705, COSV99520975; called by muse, mutect2
- GAA | c.185G>A p.R62K | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1489055645, COSV100163533; called by muse, mutect2, varscan2
- GABRQ | c.662C>T p.A221V | Missense Mutation (SNP) | VAF 13/120 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.227); catalogued as COSV100941434; called by muse, mutect2, varscan2
- GAK | c.1681G>A p.D561N | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV100034063; called by muse, mutect2, varscan2
- GALNS | c.778G>A p.E260K | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as CM124268, COSV51939672, COSV99243415; called by muse, mutect2, varscan2
- GAPDHS | c.457C>T p.P153S | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.88); catalogued as rs748828647, COSV99722496; called by muse, mutect2, varscan2
- GAS2L3 | c.1901C>T p.T634I | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.08); catalogued as COSV99903167; called by muse, mutect2, varscan2
- GATAD2A | c.1619G>A p.G540D | Missense Mutation (SNP) | VAF 40/114 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs1246961274, COSV99390719; called by muse, mutect2, varscan2
- GBF1 | c.1996G>A p.E666K (on ENST00000369983 / NM_001377137.1; = p.E665K on NM_004193.3) | Missense Mutation (SNP) | VAF 7/92 reads (8%) | SIFT tolerated (0.5); PolyPhen benign (0.044); catalogued as COSV100890672; called by muse, mutect2
- GBF1 | c.5074G>A p.G1692R (on ENST00000369983 / NM_001377137.1; = p.G1691R on NM_004193.3) | Missense Mutation (SNP) | VAF 20/412 reads (5%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.953); catalogued as COSV100890674; called by muse, mutect2
- GCC1 | c.892G>A p.E298K | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.081); catalogued as COSV99133952; called by muse, mutect2
- GCK | c.337G>A p.D113N | Missense Mutation (SNP) | VAF 33/144 reads (23%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.998); catalogued as COSV100596571; called by muse, mutect2, varscan2
- GDF15 | c.670G>A p.G224S | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99416311; called by muse, mutect2, varscan2
- GDI1 | c.964C>T p.P322S | Missense Mutation (SNP) | VAF 35/111 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99341212; called by muse, mutect2, varscan2
- GFM1 | c.1390G>A p.E464K | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT tolerated (0.28); PolyPhen benign (0.14); catalogued as COSV99963181; called by muse, mutect2, varscan2
- GHRHR | c.846G>A p.W282* | Nonsense Mutation (SNP) | VAF 23/96 reads (24%) | catalogued as COSV100396775; called by muse, mutect2, varscan2
- GIT2 | c.2150C>T p.T717I (on ENST00000355312 / NM_057169.5; = p.T639I on NM_014776.5) | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious (0.05); PolyPhen benign (0.379); catalogued as COSV58083500; called by muse, mutect2
- GJA9 | c.1255C>T p.P419S | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as COSV100668176; called by muse, mutect2
- GJA9 | c.989C>T p.S330F | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.027); catalogued as COSV100668177, COSV62532158; called by muse, mutect2, varscan2
- GJD2 | c.72G>A p.R24= | Splice Region (SNP) | VAF 12/20 reads (60%) | catalogued as rs1464039146, COSV99290907; called by muse, mutect2, varscan2
- GJD4 | c.184G>A p.A62T | Missense Mutation (SNP) | VAF 16/224 reads (7%) | SIFT tolerated (0.23); PolyPhen benign (0.05); catalogued as rs1347303151, COSV58703453; called by muse, mutect2
- GLA | c.1183G>A p.G395R | Missense Mutation (SNP) | VAF 33/87 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99516601; called by muse, mutect2, varscan2
- GLA | c.293C>T p.P98L | Missense Mutation (SNP) | VAF 14/274 reads (5%) | SIFT tolerated (0.78); PolyPhen benign (0.007); catalogued as COSV99516602; called by muse, mutect2
- GLI2 | c.3376C>T p.P1126S (on ENST00000361492 / NM_001374353.1; = p.P1143S on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs770059172, COSV100082568; called by muse, mutect2, varscan2
- GLIS2 | c.416G>A p.G139E | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.031); catalogued as COSV99267850; called by muse, mutect2, varscan2
- GNAS | c.851C>T p.T284I | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.171); catalogued as COSV99671030; called by muse, mutect2, varscan2
- GNAT1 | c.401C>T p.A134V | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.03); catalogued as COSV99137965; called by muse, mutect2
- GOLGA2 | c.1492G>A p.A498T | Missense Mutation (SNP) | VAF 23/140 reads (16%) | SIFT tolerated (0.66); PolyPhen benign (0.013); catalogued as COSV101363245; called by muse, mutect2, varscan2
- GOLGA4 | c.5768C>T p.A1923V | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV100729168; called by muse, mutect2, varscan2
- GOLGB1 | c.6578G>A p.S2193N | Missense Mutation (SNP) | VAF 51/175 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100511530; called by muse, mutect2, varscan2
- GON4L | c.3922G>A p.G1308S | Missense Mutation (SNP) | VAF 6/95 reads (6%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.003); catalogued as COSV99675760; called by muse, mutect2
- GOT2 | c.1020G>A p.W340* | Nonsense Mutation (SNP) | VAF 16/342 reads (5%) | catalogued as COSV99804012; called by muse, mutect2
- GPAT2 | c.75G>A p.W25* | Nonsense Mutation (SNP) | VAF 8/19 reads (42%) | catalogued as COSV100853356; called by muse, mutect2, varscan2
- GPBAR1 | c.365G>A p.G122E | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.842); catalogued as COSV99946519; called by muse, mutect2
- GPC3 | c.851G>A p.G284D | Missense Mutation (SNP) | VAF 45/146 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100893569; called by muse, mutect2, varscan2
- GPR156 | c.1246G>A p.V416I | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated (0.41); PolyPhen benign (0.037); catalogued as COSV100251725; called by muse, mutect2, varscan2
- GPR158 | c.58G>A p.G20R | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.019); catalogued as COSV100894290; called by muse, mutect2, varscan2
- GPR83 | c.583A>T p.T195S | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0.021); catalogued as COSV99703957; called by muse, mutect2, varscan2
- GPRASP1 | c.2327G>A p.G776E | Missense Mutation (SNP) | VAF 46/128 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100851078, COSV100851080; called by muse, mutect2, varscan2
- GPRASP2 | c.292C>T p.P98S | Missense Mutation (SNP) | VAF 61/158 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as COSV100176946; called by muse, mutect2, varscan2
- GPRIN2 | c.1120G>A p.E374K | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.342); catalogued as rs782298892, COSV100966473; called by muse, mutect2, varscan2
- GPX8 | c.574C>T p.P192S | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.212); catalogued as rs1448547348, COSV99697416; called by muse, mutect2, varscan2
- GRAMD4 | c.466+1G>A p.X156_splice | Splice Site (SNP) | VAF 22/54 reads (41%) | catalogued as rs1490246346, COSV100730654; called by muse, varscan2
- GRIK1 | c.2164G>A p.A722T | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0.095); catalogued as rs763390555, COSV100517967; called by muse, mutect2, varscan2
- GRIN2A | c.2761G>A p.A921T | Missense Mutation (SNP) | VAF 63/191 reads (33%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs1419416460, COSV100411072; called by muse, mutect2, varscan2
- GRIN2A | c.1005C>T p.H335= | Splice Region (SNP) | VAF 6/35 reads (17%) | catalogued as rs1432275575, COSV100411073; called by muse, mutect2, varscan2
- GRM7 | c.716C>T p.T239M | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs1235954876, COSV100738665; called by muse, mutect2, varscan2
- GRN | c.194C>T p.A65V | Missense Mutation (SNP) | VAF 35/109 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.448); catalogued as rs1567885592, COSV99275119; called by muse, mutect2, varscan2
- GRSF1 | c.1147G>A p.E383K | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.041); catalogued as COSV99636060; called by muse, mutect2, varscan2
- GTF2H1 | c.782G>A p.G261E | Missense Mutation (SNP) | VAF 55/112 reads (49%) | SIFT tolerated (0.16); PolyPhen benign (0.184); catalogued as COSV99786640; called by muse, mutect2, varscan2
- GTF3C1 | c.610G>A p.V204I | Missense Mutation (SNP) | VAF 29/95 reads (31%) | SIFT tolerated (0.34); PolyPhen benign (0.388); catalogued as COSV100649708; called by muse, mutect2, varscan2
- GTPBP1 | c.886G>A p.A296T | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as COSV99323492, COSV99323615; called by muse, mutect2
- GUCY1A2 | c.2038G>A p.E680K | Missense Mutation (SNP) | VAF 14/158 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.605); catalogued as COSV56499223; called by muse, mutect2
- GYS1 | c.986C>T p.A329V | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99621208; called by muse, mutect2, varscan2
- HAL | c.1285C>T p.P429S | Missense Mutation (SNP) | VAF 28/85 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764478010, COSV99701658; called by muse, mutect2, varscan2
- HAO2 | c.923C>T p.A308V | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.577); catalogued as rs1205381823, COSV100378284; called by muse, mutect2, varscan2
- HAS1 | c.1004C>T p.T335I | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.603); catalogued as COSV99708602; called by muse, mutect2, varscan2
- HAVCR2 | c.662C>T p.A221V | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT tolerated (0.65); PolyPhen benign (0.007); catalogued as COSV100324989; called by muse, mutect2, varscan2
- HDAC6 | c.926G>A p.W309* | Nonsense Mutation (SNP) | VAF 16/46 reads (35%) | catalogued as COSV100491266; called by muse, mutect2, varscan2
- HDAC9 | c.2577+1G>A p.X859_splice | Splice Site (SNP) | VAF 13/57 reads (23%) | catalogued as COSV101287552; called by muse, mutect2, varscan2
- HEATR5A | c.1586G>A p.G529E | Missense Mutation (SNP) | VAF 29/191 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.358); catalogued as COSV101120545; called by muse, mutect2, varscan2
- HEBP1 | c.104C>T p.A35V | Missense Mutation (SNP) | VAF 41/107 reads (38%) | SIFT tolerated (0.27); PolyPhen benign (0.074); catalogued as COSV99185776; called by muse, mutect2, varscan2
- HECTD4 | c.1429C>T p.L477F | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV101108374; called by muse, mutect2, varscan2
- HECW2 | c.2158C>T p.P720S | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.01); catalogued as rs1301715926, COSV99649047; called by muse, mutect2, varscan2
- HELB | c.1852A>G p.I618V | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.066); catalogued as COSV99922226; called by muse, mutect2, varscan2
- HERC1 | c.5779C>T p.P1927S | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT tolerated (0.77); PolyPhen probably damaging (0.994); catalogued as COSV101496912; called by muse, mutect2
- HERC2 | c.9515G>A p.G3172D | Missense Mutation (SNP) | VAF 17/193 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs890508983, COSV99876719; called by muse, mutect2
- HGSNAT | c.449C>T p.A150V | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV101108364; called by muse, mutect2, varscan2
- HIF3A | c.16C>T p.Q6* | Nonsense Mutation (SNP) | VAF 22/54 reads (41%) | catalogued as rs1298937203, COSV99356064; called by muse, mutect2, varscan2
- HIF3A | c.1715C>T p.T572I (on ENST00000377670 / NM_152795.4; = p.T503I on NM_022462.4) | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.011); catalogued as COSV99356066; called by muse, mutect2, varscan2
- HIVEP1 | c.6302G>A p.S2101N | Missense Mutation (SNP) | VAF 6/116 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV101045744; called by muse, mutect2
- HIVEP1 | c.7114G>A p.G2372S | Missense Mutation (SNP) | VAF 7/108 reads (6%) | SIFT tolerated (0.21); PolyPhen benign (0.111); catalogued as rs1403575918, COSV101045745; called by muse, mutect2
- HLCS | c.1424C>T p.T475I | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.792); catalogued as COSV100358616; called by muse, mutect2, varscan2
- HMBS | c.976G>A p.G326R | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT tolerated (0.41); PolyPhen benign (0.031); catalogued as COSV99598197; called by muse, mutect2, varscan2
- HMGB1 | c.238C>T p.P80S | Missense Mutation (SNP) | VAF 33/95 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.08); catalogued as COSV100361037; called by muse, mutect2, varscan2
- HNRNPA1 | c.671G>A p.G224D | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV99267873; called by muse, mutect2, varscan2
- HNRNPA2B1 | c.361G>A p.E121K (on ENST00000354667 / NM_031243.3; = p.E109K on NM_002137.4) | Missense Mutation (SNP) | VAF 21/249 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV100523018; called by muse, mutect2
- HNRNPA3 | c.308G>A p.R103H | Missense Mutation (SNP) | VAF 14/116 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.053); catalogued as rs1175881536, COSV66821225; called by muse, mutect2, varscan2
- HNRNPH2 | c.1342C>T p.L448F | Missense Mutation (SNP) | VAF 63/195 reads (32%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.029); catalogued as COSV100347269; called by muse, mutect2, varscan2
- HNRNPLL | c.895C>T p.P299S | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.031); catalogued as rs1480251973, COSV99696704; called by muse, mutect2, varscan2
- HNRNPUL2 | c.1510G>A p.D504N | Missense Mutation (SNP) | VAF 10/192 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.23); catalogued as rs1404325478, COSV100079856; called by muse, mutect2
- HOXA6 | c.458G>A p.S153N | Missense Mutation (SNP) | VAF 8/148 reads (5%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV99762497; called by muse, mutect2
- HOXB8 | c.406C>T p.P136S | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99494201; called by muse, mutect2
- HOXD12 | c.43C>T p.L15F | Missense Mutation (SNP) | VAF 40/99 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.559); catalogued as rs769569431, COSV101184351; called by muse, varscan2
- HPS5 | c.646G>A p.D216N (on ENST00000349215 / NM_181507.2; = p.D102N on NM_007216.4) | Missense Mutation (SNP) | VAF 19/32 reads (59%) | SIFT tolerated (0.07); PolyPhen benign (0.059); catalogued as rs139112919; called by muse, mutect2, varscan2
- HS1BP3 | c.385C>T p.P129S | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs749624283, COSV100398108; called by muse, mutect2, varscan2
- HSD17B8 | c.41C>T p.A14V | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as rs765641312, COSV100761863; called by muse, mutect2
- HSPA1B | c.52G>A p.V18M | Missense Mutation (SNP) | VAF 6/77 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.983); catalogued as COSV100989283; called by muse, mutect2
- HTR2B | c.487G>A p.A163T | Missense Mutation (SNP) | VAF 11/245 reads (4%) | SIFT tolerated (0.6); PolyPhen possibly damaging (0.9); catalogued as COSV99295448; called by muse, mutect2
- HTT | c.7245G>A p.V2415= | Splice Region (SNP) | VAF 25/143 reads (17%) | catalogued as rs767418451, COSV100751259; called by muse, mutect2, varscan2
- HUWE1 | c.6182G>A p.G2061D | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.622); catalogued as COSV99474206; called by muse, mutect2, varscan2
- IBTK | c.2734C>T p.L912F | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.542); catalogued as rs751833417, COSV100091512; called by muse, mutect2, varscan2
- IDH3B | c.62G>A p.G21E | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT tolerated (0.18); PolyPhen benign (0.023); catalogued as COSV101077395; called by muse, mutect2, varscan2
- IDI2 | c.584C>T p.P195L | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs138472250; called by muse, mutect2, varscan2
- IFNGR2 | c.136G>A p.V46I | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0.103); catalogued as COSV99274885; called by muse, mutect2, varscan2
- IFNLR1 | c.1010G>A p.G337D | Missense Mutation (SNP) | VAF 53/134 reads (40%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as COSV100552312; called by muse, mutect2, varscan2
- IFRD1 | c.1104G>A p.W368* | Nonsense Mutation (SNP) | VAF 47/193 reads (24%) | catalogued as COSV99134407; called by muse, mutect2, varscan2
- IFT57 | c.242G>A p.G81D | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1163148623, COSV99198203; called by muse, mutect2, varscan2
- IGF2R | c.2663G>A p.R888K | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.696); catalogued as COSV100808188, COSV100808416; called by muse, mutect2, varscan2
- IGF2R | c.5768C>T p.A1923V | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as rs368781979; called by muse, mutect2, varscan2
- IGF2R | c.5965C>T p.P1989S | Missense Mutation (SNP) | VAF 36/79 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100808192; called by muse, mutect2, varscan2
- IGLV6-57 | c.232G>A p.V78I | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.262); catalogued as rs766280696, COSV101135330; called by muse, mutect2, varscan2
- IL1RAP | c.1271C>T p.T424I | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as COSV99300220; called by muse, mutect2, varscan2
- IL1RN | c.398C>T p.T133I (on ENST00000409930 / NM_173842.3; = p.T115I on NM_000577.5) | Missense Mutation (SNP) | VAF 52/112 reads (46%) | SIFT tolerated (0.14); PolyPhen benign (0.202); catalogued as COSV99381832; called by muse, mutect2
- IL20RA | c.1136G>A p.G379D | Missense Mutation (SNP) | VAF 15/101 reads (15%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs373486228; called by muse, mutect2, varscan2
- IL22RA2 | c.526G>A p.V176I | Missense Mutation (SNP) | VAF 18/119 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.873); catalogued as COSV99760831; called by muse, mutect2, varscan2
- ILF3 | c.1468C>T p.P490S | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.25); PolyPhen benign (0.204); catalogued as COSV99139468; called by muse, mutect2, varscan2
- INHA | c.131C>T p.P44L | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.425); catalogued as rs1342413931, COSV54732558; called by muse, mutect2
- INPPL1 | c.1945C>T p.R649* | Nonsense Mutation (SNP) | VAF 12/42 reads (29%) | catalogued as rs777831045, COSV53356893; called by muse, mutect2, varscan2
- INTS2 | c.2716C>T p.Q906* | Nonsense Mutation (SNP) | VAF 8/25 reads (32%) | catalogued as COSV52150911, COSV99248827; called by muse, mutect2, varscan2
- INTS6 | c.1906G>A p.A636T | Missense Mutation (SNP) | VAF 33/72 reads (46%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as COSV100247266; called by muse, mutect2, varscan2
- INTS6L | c.197G>A p.W66* | Nonsense Mutation (SNP) | VAF 6/94 reads (6%) | catalogued as COSV100878320; called by muse, mutect2
- INTS7 | c.1471G>A p.V491M | Missense Mutation (SNP) | VAF 41/61 reads (67%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.558); catalogued as COSV100877576; called by muse, mutect2, varscan2
- INTS9 | c.398G>A p.G133D | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1344147958, COSV101274004; called by muse, mutect2, varscan2
- INVS | c.695G>A p.G232E | Missense Mutation (SNP) | VAF 34/102 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV52450697, COSV99318259; called by muse, mutect2, varscan2
- IPO13 | c.1034G>A p.G345D | Missense Mutation (SNP) | VAF 10/111 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as COSV100961353; called by muse, mutect2
- IPO4 | c.643C>T p.P215S | Missense Mutation (SNP) | VAF 70/234 reads (30%) | SIFT tolerated (0.57); PolyPhen benign (0.01); catalogued as COSV55780776; called by muse, mutect2, varscan2
- IPO5 | c.1421C>T p.P474L | Missense Mutation (SNP) | VAF 37/105 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99847680; called by muse, mutect2, varscan2
- IQCF2 | c.250G>A p.V84M | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as COSV100291107; called by muse, mutect2, varscan2
- IQCN | c.2681G>A p.G894D | Missense Mutation (SNP) | VAF 11/128 reads (9%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.915); catalogued as rs1037737745, COSV100828423; called by muse, mutect2
- IQGAP3 | c.1993+1G>A p.X665_splice | Splice Site (SNP) | VAF 6/90 reads (7%) | catalogued as COSV100752381; called by muse, mutect2
- IRAK4 | c.584G>A p.G195E | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101471845; called by muse, mutect2
- IRF2BP2 | c.1517G>A p.C506Y | Missense Mutation (SNP) | VAF 34/58 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100784407; called by muse, mutect2, varscan2
- IRS4 | c.1982G>A p.R661K | Missense Mutation (SNP) | VAF 143/406 reads (35%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.001); catalogued as COSV100929733; called by muse, mutect2, varscan2
- IRX5 | c.638C>T p.P213L | Missense Mutation (SNP) | VAF 11/166 reads (7%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV100315657, COSV100316004; called by muse, mutect2
- IRX5 | c.1091G>A p.G364E | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.22); catalogued as COSV58060367; called by muse, mutect2
- ISCU | c.71C>T p.P24L | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.09); catalogued as rs1031043758; called by muse, mutect2, varscan2
- ITCH | c.799C>T p.P267S (on ENST00000262650 / NM_001257137.3; = p.P226S on NM_031483.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/105 reads (30%) | SIFT tolerated (0.48); PolyPhen benign (0.293); catalogued as COSV99393173; called by muse, mutect2, varscan2
- ITGA1 | c.2365G>A p.V789I | Missense Mutation (SNP) | VAF 9/127 reads (7%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.536); catalogued as COSV99252169; called by muse, mutect2
- ITGA3 | c.2380C>T p.P794S | Missense Mutation (SNP) | VAF 33/120 reads (28%) | SIFT tolerated (0.66); PolyPhen probably damaging (0.996); catalogued as rs1174089345, COSV99144233; called by muse, mutect2, varscan2
- ITGA6 | c.661C>T p.Q221* | Nonsense Mutation (SNP) | VAF 21/70 reads (30%) | catalogued as COSV99906096; called by muse, mutect2, varscan2
- ITGAE | c.1808G>A p.G603D | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT tolerated (0.42); PolyPhen benign (0.088); catalogued as rs770141468, COSV99561547; called by muse, mutect2, varscan2
- ITIH5 | c.1882C>T p.P628S | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT tolerated (0.7); PolyPhen benign (0.007); catalogued as rs755868465, COSV99905780; called by muse, mutect2, varscan2
- ITPRID1 | c.1129C>T p.H377Y | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs765135134, COSV100087530; called by muse, mutect2, varscan2
- JAK1 | c.3422G>A p.S1141N | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV99605669; called by muse, varscan2
- JAK1 | c.3370G>A p.V1124I | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT tolerated (0.51); PolyPhen benign (0.007); catalogued as COSV53806546; called by muse, varscan2
- JAKMIP1 | c.1765G>A p.D589N | Missense Mutation (SNP) | VAF 13/254 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99290792; called by muse, mutect2
- JMJD1C | c.557C>T p.P186L | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.82); catalogued as rs1464601660, COSV101232476; called by muse, mutect2, varscan2
- KCNA6 | c.483G>A p.W161* | Nonsense Mutation (SNP) | VAF 14/74 reads (19%) | catalogued as COSV99768979; called by muse, mutect2, varscan2
- KCNA6 | c.856C>T p.P286S | Missense Mutation (SNP) | VAF 15/147 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99768981; called by muse, mutect2, varscan2
- KCNA7 | c.745G>A p.A249T | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV99672036; called by muse, mutect2
- KCNH6 | c.2891C>T p.S964F | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.417); catalogued as rs1216590311, COSV100121265; called by muse, mutect2, varscan2
- KCNJ14 | c.802C>T p.L268F | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.997); catalogued as rs775442705, COSV100655825; called by muse, mutect2, varscan2
- KCNJ3 | c.1301C>T p.P434L | Missense Mutation (SNP) | VAF 11/120 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV99039255, COSV99716502; called by muse, mutect2
- KCNJ6 | c.934G>A p.V312M | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99900546; called by muse, mutect2, varscan2
- KCNQ2 | c.1787G>A p.G596D (on ENST00000359125 / NM_172107.4; = p.G568D on NM_004518.6) | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV100610548, COSV100610626; called by muse, mutect2, varscan2
- KCNQ4 | c.956G>A p.G319D | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1308296992, COSV100714427; called by muse, mutect2
- KCTD16 | c.994C>T p.P332S | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.992); catalogued as COSV101568895; called by muse, mutect2, varscan2
- KCTD19 | c.993G>A p.W331* | Nonsense Mutation (SNP) | VAF 22/65 reads (34%) | catalogued as rs1306440277, COSV100431226; called by muse, mutect2, varscan2
- KDM5A | c.2531G>A p.R844Q | Missense Mutation (SNP) | VAF 42/155 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.19); catalogued as rs370349922, COSV101238743; called by muse, mutect2, varscan2
- KDM5B | c.415G>A p.E139K | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.399); catalogued as rs1354864063, COSV52510081; called by muse, mutect2, varscan2
- KDR | c.2373+1G>A p.X791_splice | Splice Site (SNP) | VAF 32/87 reads (37%) | catalogued as COSV99818694; called by muse, mutect2, varscan2
- KHDC4 | c.1508G>A p.G503E | Missense Mutation (SNP) | VAF 69/182 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.214); catalogued as rs768198934, COSV64165300; called by muse, mutect2, varscan2
- KIAA0895 | c.544C>T p.P182S (on ENST00000297063 / NM_001100425.2; = p.P131S on NM_015314.3) | Missense Mutation (SNP) | VAF 42/193 reads (22%) | SIFT tolerated, low confidence (0.8); PolyPhen benign (0.009); catalogued as COSV99767203; called by muse, mutect2, varscan2
- KIAA1109 | c.658C>T p.P220S | Missense Mutation (SNP) | VAF 17/112 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1258511894, COSV99176004; called by muse, mutect2, varscan2
- KIAA1549 | c.2504G>A p.G835D | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.115); catalogued as rs1165526008, COSV99652008; called by muse, mutect2, varscan2
- KIAA1614 | c.1298G>A p.G433E | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); catalogued as COSV62550931; called by muse, mutect2, varscan2
- KIF11 | c.1217+1G>A p.X406_splice | Splice Site (SNP) | VAF 25/62 reads (40%) | catalogued as COSV99586166; called by muse, mutect2, varscan2
- KIF12 | c.1771C>T p.P591S (on ENST00000640217; = p.P453S on NM_138424.1) | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100936276, COSV65117638; called by muse, mutect2, varscan2
- KIF14 | c.2537C>T p.A846V | Missense Mutation (SNP) | VAF 39/98 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs1433504961, COSV100951083; called by muse, mutect2, varscan2
- KIF16B | c.2578A>G p.I860V | Missense Mutation (SNP) | VAF 63/197 reads (32%) | SIFT tolerated, low confidence (0.75); PolyPhen benign (0); catalogued as rs200360811; called by muse, mutect2, varscan2
- KIF17 | c.779C>T p.A260V | Missense Mutation (SNP) | VAF 45/107 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1372741853, COSV99929773; called by muse, mutect2, varscan2
- KIF1A | c.1243G>A p.A415T | Missense Mutation (SNP) | VAF 31/67 reads (46%) | SIFT tolerated (0.36); PolyPhen benign (0.197); catalogued as rs749112240, COSV100242321; called by muse, mutect2, varscan2
- KIF1B | c.922G>A p.D308N (on ENST00000377086 / NM_001365952.1; = p.D302N on NM_015074.3) | Missense Mutation (SNP) | VAF 41/133 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); catalogued as rs1198541796, COSV99824205; called by muse, mutect2, varscan2
- KIF1C | c.3014C>T p.P1005L | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated, low confidence (0.12); PolyPhen probably damaging (0.981); catalogued as COSV100297304; called by muse, mutect2, varscan2
- KIF20B | c.1852G>A p.A618T | Missense Mutation (SNP) | VAF 18/121 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.13); catalogued as rs371085455; called by muse, mutect2, varscan2
- KIF20B | c.2872G>A p.E958K (on ENST00000371728 / NM_001284259.2; = p.E918K on NM_016195.4) | Missense Mutation (SNP) | VAF 16/105 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.006); catalogued as rs775282828, COSV99590737; called by muse, mutect2, varscan2
- KIF26A | c.1666C>T p.P556S | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV100180948, COSV59471123; called by muse, mutect2, varscan2
- KIF3C | c.1453G>A p.E485K | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.787); catalogued as COSV99267959; called by muse, mutect2, varscan2
- KIRREL1 | c.998G>A p.G333E | Missense Mutation (SNP) | VAF 41/91 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100780118; called by muse, mutect2, varscan2
- KIZ | c.1210G>A p.G404R | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.23); PolyPhen benign (0.031); catalogued as COSV99852413; called by muse, mutect2, varscan2
- KLF12 | c.506C>T p.P169L | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.981); catalogued as COSV100888676; called by muse, mutect2, varscan2
- KLF7 | c.34G>A p.E12K | Missense Mutation (SNP) | VAF 44/111 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.185); catalogued as COSV100519161; called by muse, mutect2, varscan2
- KLHL22 | c.172G>A p.G58S | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.769); catalogued as COSV100186258, COSV61020742; called by muse, mutect2, varscan2
- KLHL34 | c.716G>A p.G239D | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.23); PolyPhen benign (0.366); catalogued as rs1442471871, COSV101069998; called by muse, mutect2, varscan2
- KMT2C | c.2652+1G>A p.X884_splice | Splice Site (SNP) | VAF 20/138 reads (14%) | catalogued as rs1267675605, COSV100076485; called by muse, varscan2
- KMT2D | c.12724C>T p.P4242S | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.007); catalogued as rs572421556, COSV56475993; called by muse, mutect2, varscan2
- KNL1 | c.5890G>A p.A1964T (on ENST00000346991 / NM_170589.5; = p.A1938T on NM_144508.5) | Missense Mutation (SNP) | VAF 62/187 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.283); catalogued as rs766288500, COSV100707043; called by muse, mutect2, varscan2
- KRIT1 | c.829A>G p.S277G | Missense Mutation (SNP) | VAF 22/104 reads (21%) | SIFT tolerated (0.35); PolyPhen benign (0.057); catalogued as COSV100388943; called by muse, mutect2, varscan2
- KRT31 | c.1202C>T p.P401L | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV52438737, COSV99290157; called by muse, mutect2, varscan2
- KRT4 | c.362C>T p.P121L | Missense Mutation (SNP) | VAF 16/117 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs757780016, COSV53407294; called by muse, mutect2, varscan2
- KRT6B | c.1054G>A p.A352T | Missense Mutation (SNP) | VAF 62/204 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as COSV99360998; called by muse, mutect2, varscan2
- KRTAP1-1 | c.466C>T p.P156S | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV100092283; called by muse, mutect2, varscan2
- KRTAP4-4 | c.67C>T p.P23S | Missense Mutation (SNP) | VAF 15/131 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.113); catalogued as COSV101180576; called by muse, mutect2, varscan2
- KRTAP9-2 | c.389G>A p.G130D | Missense Mutation (SNP) | VAF 90/233 reads (39%) | SIFT tolerated (0.22); PolyPhen benign (0.172); catalogued as COSV100893249; called by muse, mutect2, varscan2
- KTN1 | c.2158C>T p.L720F | Missense Mutation (SNP) | VAF 44/100 reads (44%) | SIFT tolerated (0.37); PolyPhen benign (0.014); catalogued as COSV101255441; called by muse, mutect2, varscan2
- KY | c.1853C>T p.T618I | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.091); catalogued as rs745511733, COSV101415038; called by muse, mutect2, varscan2
- LACTB | c.931G>A p.D311N | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV99979072; called by muse, mutect2, varscan2
- LAMA3 | c.1765G>A p.A589T | Missense Mutation (SNP) | VAF 11/114 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.205); catalogued as COSV100557668; called by muse, mutect2
- LAMB2 | c.2480G>A p.G827D | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs774709354, COSV100026498; called by muse, mutect2, varscan2
- LAMB3 | c.504G>A p.W168* | Nonsense Mutation (SNP) | VAF 6/81 reads (7%) | catalogued as COSV100620530; called by muse, mutect2
- LANCL1 | c.610C>T p.P204S | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs200162143, COSV99286467; called by muse, mutect2, varscan2
- LARP7 | c.593G>A p.G198D | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100135332; called by muse, mutect2, varscan2
- LCA5 | c.995G>A p.G332E | Missense Mutation (SNP) | VAF 9/168 reads (5%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.868); catalogued as rs1283987592, COSV100878373; called by muse, mutect2
- LCMT2 | c.1717C>T p.L573F | Missense Mutation (SNP) | VAF 8/99 reads (8%) | SIFT tolerated (0.73); PolyPhen possibly damaging (0.877); catalogued as rs1238873745, COSV59790664; called by muse, mutect2
- LCN12 | c.114+1G>A p.X38_splice | Splice Site (SNP) | VAF 7/24 reads (29%) | catalogued as COSV100861344; called by muse, mutect2, varscan2
- LCN15 | c.112T>C p.Y38H | Missense Mutation (SNP) | VAF 27/99 reads (27%) | SIFT tolerated (0.34); PolyPhen benign (0.094); catalogued as rs775005025, COSV100293631; called by muse, mutect2, varscan2
- LDHAL6A | c.454G>A p.G152R | Missense Mutation (SNP) | VAF 37/62 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.579); catalogued as COSV99324240; called by muse, mutect2, varscan2
- LETMD1 | c.42G>A p.W14* | Nonsense Mutation (SNP) | VAF 12/135 reads (9%) | catalogued as COSV50399507; called by muse, mutect2
- LGMN | c.493G>A p.D165N | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.461); catalogued as COSV58402869; called by muse, mutect2, varscan2
- LGR4 | c.1784C>T p.T595I | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs369900849; called by muse, mutect2, varscan2
- LIF | c.601G>A p.A201T | Missense Mutation (SNP) | VAF 7/128 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.161); catalogued as COSV50776592; called by muse, mutect2
- LIN52 | c.131G>A p.S44N | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.028); catalogued as COSV101617372; called by muse, mutect2, varscan2
- LIN54 | c.319C>T p.P107S | Missense Mutation (SNP) | VAF 32/233 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.262); catalogued as COSV100465027, COSV61202742; called by muse, mutect2, varscan2
- LINS1 | c.935G>A p.G312D | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); catalogued as COSV100130555; called by muse, mutect2, varscan2
- LIPC | c.605G>A p.G202E | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV54421479; called by muse, mutect2
- LIPH | c.1268+1G>A p.X423_splice | Splice Site (SNP) | VAF 21/67 reads (31%) | catalogued as COSV99956326; called by muse, mutect2, varscan2
- LMAN1L | c.691G>A p.V231I | Missense Mutation (SNP) | VAF 35/147 reads (24%) | SIFT tolerated (0.92); PolyPhen benign (0.106); catalogued as COSV100547594, COSV100547844; called by muse, mutect2, varscan2
- LMO7 | c.2027G>A p.R676K (on ENST00000357063; = p.R406K on NM_015842.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100413858; called by muse, mutect2
- LMO7 | c.4654C>T p.P1552S (on ENST00000357063; = p.P1233S on NM_005358.5) | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.287); catalogued as rs373867452; called by muse, mutect2, varscan2
- LMOD1 | c.317G>A p.R106K | Missense Mutation (SNP) | VAF 41/102 reads (40%) | SIFT tolerated (0.96); PolyPhen benign (0.007); catalogued as COSV100939271; called by muse, mutect2, varscan2
- LONP2 | c.1795+1G>A p.X599_splice | Splice Site (SNP) | VAF 50/138 reads (36%) | catalogued as rs766170631, COSV99589520; called by muse, mutect2, varscan2
- LOXL4 | c.374C>T p.S125L | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.243); catalogued as COSV53257343; called by muse, mutect2, varscan2
- LRGUK | c.256G>A p.G86R | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as rs750251558, COSV99604695; called by muse, mutect2, varscan2
- LRIG2 | c.1328G>A p.S443N | Missense Mutation (SNP) | VAF 41/111 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV100743706; called by muse, mutect2, varscan2
- LRP1 | c.2329C>T p.P777S | Missense Mutation (SNP) | VAF 41/115 reads (36%) | SIFT tolerated (0.48); PolyPhen benign (0.007); catalogued as COSV99677223; called by muse, mutect2, varscan2
- LRP1 | c.10304G>A p.G3435E | Missense Mutation (SNP) | VAF 18/116 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV99677227; called by muse, mutect2, varscan2
- LRP1B | c.5885G>A p.W1962* | Nonsense Mutation (SNP) | VAF 10/136 reads (7%) | catalogued as COSV101261067; called by muse, mutect2
- LRP1B | c.248C>T p.A83V | Missense Mutation (SNP) | VAF 33/101 reads (33%) | SIFT tolerated (0.28); PolyPhen benign (0.138); catalogued as COSV101261068; called by muse, mutect2, varscan2
- LRP2 | c.12019G>A p.D4007N | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99790264; called by muse, mutect2, varscan2
- LRP2 | c.5672G>A p.G1891E | Missense Mutation (SNP) | VAF 33/78 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55548338, COSV99790265; called by muse, mutect2, varscan2
- LRP3 | c.373C>T p.P125S | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs1218735976, COSV99472482, COSV99472584; called by muse, mutect2
- LRP6 | c.3733+1G>A p.X1245_splice | Splice Site (SNP) | VAF 15/114 reads (13%) | catalogued as COSV99744499; called by muse, mutect2, varscan2
- LRP6 | c.1289C>T p.T430I | Missense Mutation (SNP) | VAF 5/67 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as COSV99744502; called by muse, mutect2
- LRPPRC | c.3234G>T p.M1078I | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV99581479; called by muse, mutect2, varscan2
- LRRC2 | c.781G>A p.E261K | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0.094); catalogued as COSV99947678; called by muse, mutect2, varscan2
- LRRC24 | c.683C>T p.T228I | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.043); catalogued as COSV99468234; called by muse, mutect2, varscan2
- LRRC27 | c.1277G>A p.S426N | Missense Mutation (SNP) | VAF 34/53 reads (64%) | SIFT tolerated (0.15); PolyPhen benign (0.017); catalogued as rs945569366, COSV100889925; called by muse, mutect2, varscan2
- LRRC32 | c.1789G>A p.D597N | Missense Mutation (SNP) | VAF 6/65 reads (9%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as COSV99477359; called by muse, mutect2
- LRRC4B | c.815C>T p.A272V | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.577); catalogued as COSV100976049; called by muse, mutect2, varscan2
- LRRC66 | c.1618G>A p.E540K | Missense Mutation (SNP) | VAF 38/155 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as COSV100603104; called by muse, mutect2, varscan2
- LRRC8A | c.2428G>A p.A810T | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.023); catalogued as rs777304358, COSV99396937; called by muse, mutect2, varscan2
- LRRIQ1 | c.5103A>T p.K1701N | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT tolerated (0.73); PolyPhen benign (0.1); catalogued as COSV101280712; called by muse, mutect2, varscan2
- LRRN2 | c.1769C>T p.A590V | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.255); catalogued as COSV100912969; called by muse, mutect2
- LRTM1 | c.503C>T p.S168F | Missense Mutation (SNP) | VAF 41/107 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as COSV99836147; called by muse, mutect2, varscan2
- LSM3 | c.272G>A p.G91D | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.717); catalogued as COSV100025593; called by muse, mutect2, varscan2
- LTB4R2 | c.214G>A p.V72M (on ENST00000528054; = p.V41M on NM_019839.5) | Missense Mutation (SNP) | VAF 22/36 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1161879488, COSV99351173; called by muse, mutect2, varscan2
- LTN1 | c.3239+1G>A p.X1080_splice | Splice Site (SNP) | VAF 25/73 reads (34%) | catalogued as rs1327334771, COSV100798221; called by muse, mutect2, varscan2
- LUZP1 | c.163G>A p.E55K | Missense Mutation (SNP) | VAF 6/128 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56504042; called by muse, mutect2
- LUZP2 | c.183C>T p.S61= | Splice Region (SNP) | VAF 10/19 reads (53%) | catalogued as COSV61195449; called by muse, mutect2
- LYST | c.2783G>A p.G928D | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (1); catalogued as rs774002145, COSV101090298; called by muse, mutect2, varscan2
- MAB21L4 | c.392C>T p.A131V | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.46); PolyPhen benign (0.007); catalogued as COSV100278707; called by muse, mutect2, varscan2
- MACF1 | c.15464G>A p.R5155K (on ENST00000372915; = p.R3088K on NM_012090.5) | Missense Mutation (SNP) | VAF 13/54 reads (24%) | catalogued as COSV57146411; called by muse, mutect2, varscan2
- MAGEA11 | c.529G>A p.E177K | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT tolerated (0.99); PolyPhen benign (0); catalogued as rs1459190681, COSV100290715; called by muse, mutect2, varscan2
- MAGEA4 | c.83C>T p.A28V | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.3); catalogued as rs772345662, COSV52340022; called by muse, mutect2, varscan2
- MAGEL2 | c.1951G>A p.G651R | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.969); catalogued as rs1397293592, COSV100046210; called by muse, mutect2, varscan2
- MAGT1 | c.205C>T p.P69S (on ENST00000618282 / NM_001367916.1; = p.P101S on NM_032121.5) | Missense Mutation (SNP) | VAF 43/264 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100800448; called by muse, mutect2, varscan2
- MANF | c.206G>A p.G69D | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as rs782244987, COSV99815089; called by muse, mutect2, varscan2
- MAP1B | c.4399C>T p.P1467S | Missense Mutation (SNP) | VAF 34/73 reads (47%) | SIFT tolerated (0.4); PolyPhen benign (0.343); catalogued as COSV99702940; called by muse, mutect2, varscan2
- MAP3K10 | c.190C>T p.P64S | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.33); PolyPhen benign (0.057); catalogued as COSV99454855; called by mutect2, varscan2
- MAP3K11 | c.668C>T p.A223V | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); catalogued as rs1398367524, COSV58420689; called by muse, mutect2, varscan2
- MAP3K6 | c.2227G>A p.D743N | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.163); catalogued as COSV100709450; called by muse, mutect2, varscan2
- MAP7D1 | c.2516-1G>A p.X839_splice | Splice Site (SNP) | VAF 76/182 reads (42%) | catalogued as COSV100294814; called by muse, varscan2
- MAPK10 | c.518C>T p.A173V (on ENST00000359221 / NM_001351625.2; = p.A211V on NM_002753.5) | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100175431; called by muse, mutect2, varscan2
- MAPK8IP3 | c.1318G>A p.V440M | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99169755; called by muse, mutect2, varscan2
- MAPK8IP3 | c.2779C>T p.P927S | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.092); catalogued as rs373749828; called by muse, mutect2, varscan2
- MAPKAPK3 | c.360-1G>A p.X120_splice | Splice Site (SNP) | VAF 18/40 reads (45%) | catalogued as COSV100781789; called by muse, mutect2, varscan2
- MARCHF6 | c.2128G>A p.V710I | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV99930163; called by muse, mutect2, varscan2
- MARK1 | c.685C>T p.Q229* | Nonsense Mutation (SNP) | VAF 6/37 reads (16%) | catalogued as COSV100857566; called by muse, mutect2, varscan2
- MARVELD3 | c.880C>T p.R294W | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99194853; called by muse, mutect2, varscan2
- MAST2 | c.1156C>T p.L386F | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100788772; called by muse, mutect2, varscan2
- MBOAT2 | c.1480G>A p.G494R | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.154); catalogued as rs746452770, COSV100020656; called by muse, mutect2, varscan2
- MCCC1 | c.1117G>A p.E373K | Missense Mutation (SNP) | VAF 29/107 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.021); catalogued as COSV99660057; called by muse, mutect2, varscan2
- MCEE | c.181G>A p.A61T | Missense Mutation (SNP) | VAF 11/169 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.9); catalogued as COSV99731290; called by muse, mutect2
- MCF2L | c.2419G>A p.A807T (on ENST00000375608; = p.A775T on NM_024979.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.651); catalogued as COSV99996167; called by muse, mutect2, varscan2
- MCHR1 | c.712G>A p.A238T | Missense Mutation (SNP) | VAF 7/97 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.696); catalogued as rs1394320088, COSV99967904; called by muse, mutect2
- MDGA1 | c.2333C>T p.A778V | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT deleterious (0.05); PolyPhen benign (0.3); catalogued as rs767155231, COSV51801315; called by muse, mutect2, varscan2
- MDN1 | c.9530G>A p.G3177D | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated (0.62); PolyPhen benign (0.001); catalogued as rs948346815, COSV101021831; called by muse, mutect2, varscan2
- MECP2 | c.61C>T p.L21F | Missense Mutation (SNP) | VAF 8/132 reads (6%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.043); catalogued as rs782396283, COSV100318512; called by muse, mutect2
- MED12 | c.1478G>A p.G493E | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.314); catalogued as COSV100379963; called by muse, mutect2, varscan2
- MED13 | c.6103G>A p.G2035S | Missense Mutation (SNP) | VAF 20/125 reads (16%) | SIFT tolerated (0.48); PolyPhen benign (0.133); catalogued as COSV101181398; called by muse, mutect2, varscan2
- MED13L | c.5887C>T p.P1963S | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1358776063, COSV99930168; called by muse, mutect2, varscan2
- MED16 | c.1771+1G>A p.X591_splice | Splice Site (SNP) | VAF 25/80 reads (31%) | catalogued as COSV99516280; called by muse, mutect2, varscan2
- MED25 | c.1073C>T p.P358L | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.084); catalogued as COSV100457987; called by muse, mutect2, varscan2
- MEI1 | c.1150G>A p.E384K | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100300353; called by muse, mutect2, varscan2
- MELK | c.1162C>T p.P388S | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.164); catalogued as COSV53203230; called by muse, mutect2, varscan2
- MEST | c.595G>A p.V199M | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as COSV99784417; called by muse, mutect2
1,549 further variants in this file (800 protein-altering or splice-affecting, 695 silent, 54 other) are not listed here.
